Somatic mutation profile of tumor specimen TCGA-BR-4362-01A (aliquot TCGA-BR-4362-01A-01D-1158-08) from TCGA case TCGA-BR-4362, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; Tumor grade: G3; Age at diagnosis: 74.4 years (27,179 days).
Specimen TCGA-BR-4362-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 52ca98c5-af38-481f-b95e-a4bdb956f43b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-4362-11A (Solid Tissue Normal), aliquot TCGA-BR-4362-11A-01D-1158-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1b2c506-63cb-4ab1-b791-937d46f73f57

The open-access MAF lists 1,811 somatic variants for this specimen: 1,413 protein-altering or splice-affecting, 350 silent, 48 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 941, Silent 350, Frame Shift Del 313, Frame Shift Ins 63, Nonsense Mutation 44, Intron 24, Splice Site 20, In Frame Del 18, Splice Region 12, RNA 8, 3'Flank 5, 3'UTR 4.

Variants (750 of 1,811; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AP1S1 | c.364del p.D122Mfs*11 | Frame Shift Del (DEL) | VAF 15/65 reads (23%) | catalogued as rs767358930; ClinVar: likely pathogenic; called by mutect2, varscan2
- ARG1 | c.703G>A p.G235R | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs104893948, CM920105, CM962599, CX165256, COSV51580679; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 23/125 reads (18%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- BLM | c.1544del p.N515Mfs*16 | Frame Shift Del (DEL) | VAF 34/106 reads (32%) | catalogued as rs367543043; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- BRCA2 | c.2271_2272del p.L759Ffs*3 | Frame Shift Del (DEL) | VAF 25/126 reads (20%) | catalogued as rs886040420; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- COL7A1 | c.6081del p.P2029Lfs*177 | Frame Shift Del (DEL) | VAF 5/29 reads (17%) | catalogued as rs780623622, CD961934; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- DYSF | c.4200del p.I1401Sfs*47 | Frame Shift Del (DEL) | VAF 19/80 reads (24%) | catalogued as rs398123786, CM053841; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ERBB3 | c.310G>A p.V104M | Missense Mutation (SNP) | VAF 59/216 reads (27%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen possibly damaging (0.64); catalogued as rs1057519893, COSV57246387, COSV57246465, COSV57253558; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HNF1B | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 60/210 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); catalogued as rs914046953; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- HUWE1 | c.329G>A p.R110Q | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1557036768, CM155939, COSV53337343; ClinVar: pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.6955C>T p.R2319* | Nonsense Mutation (SNP) | VAF 44/214 reads (21%) | catalogued as rs398123383, CM981166, COSV70341208; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAN2B1 | c.2402dup p.S802Qfs*129 | Frame Shift Ins (INS) | VAF 15/67 reads (22%) | catalogued as rs797044680; ClinVar: likely pathogenic / pathogenic; called by mutect2, pindel, varscan2
- MFSD8 | c.416G>A p.R139H | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749704755, CM091912, COSV56550601; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 8/20 reads (40%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- NEK1 | c.1908del p.V637Cfs*34 | Frame Shift Del (DEL) | VAF 14/28 reads (50%) | catalogued as rs775849720; ClinVar: likely pathogenic; called by mutect2, varscan2
- NIPBL | c.1808del p.K603Sfs*11 | Frame Shift Del (DEL) | VAF 34/148 reads (23%) | catalogued as rs727503767; ClinVar: pathogenic; called by mutect2, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 23/101 reads (23%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PEX6 | c.2440C>T p.R814* | Nonsense Mutation (SNP) | VAF 165/689 reads (24%) | catalogued as rs267608241, CM100015, COSV55102082; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.800del p.K267Rfs*9 | Frame Shift Del (DEL) | VAF 69/137 reads (50%) | catalogued as rs121913289; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- SCN5A | c.845G>A p.R282H | Missense Mutation (SNP) | VAF 17/72 reads (24%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs199473083, CM024636, COSV61118240; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SPART | c.696del p.F232Lfs*2 | Frame Shift Del (DEL) | VAF 22/149 reads (15%) | catalogued as rs770560051; ClinVar: pathogenic; called by mutect2, varscan2
- TBK1 | c.1069C>T p.R357* | Nonsense Mutation (SNP) | VAF 41/68 reads (60%) | catalogued as rs1328949478, CM152647, COSV59154007; ClinVar: pathogenic; called by muse, mutect2, varscan2
- VCP | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs121909330, CM040815, CM092553, COSV100734231, COSV62719858; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AAGAB | c.338T>C p.V113A | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as COSV56016213; called by muse, mutect2, varscan2
- AANAT | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 4/12 reads (33%) | catalogued as COSV51683852; called by muse, mutect2, varscan2
- AATK | c.2629G>A p.D877N (on ENST00000326724 / NM_001080395.3; = p.D774N on NM_004920.2) | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as rs780911896, COSV58364760; called by muse, mutect2, varscan2
- ABCA2 | c.2549T>C p.I850T (on ENST00000614293; = p.I820T on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55798456; called by muse, mutect2, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 22/86 reads (26%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCC11 | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.853); catalogued as rs552749952, COSV62321701; called by muse, mutect2, varscan2
- ABCC11 | c.973G>A p.V325M | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.045); catalogued as rs768117319, COSV62321704; called by muse, mutect2, varscan2
- ABCC4 | c.3655del p.I1219Sfs*11 | Frame Shift Del (DEL) | VAF 34/210 reads (16%) | catalogued as rs756859429, COSV65316407; called by mutect2, varscan2
- ABI1 | c.316C>T p.R106* | Nonsense Mutation (SNP) | VAF 18/69 reads (26%) | catalogued as rs779235416, COSV61015584; called by muse, mutect2, varscan2
- ABTB2 | c.2456C>A p.P819H | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54385014; called by muse, mutect2
- AC126283.2 | c.111del p.K37Nfs*65 | Frame Shift Del (DEL) | VAF 31/136 reads (23%) | catalogued as rs1560546604; called by mutect2, pindel, varscan2
- ACACB | c.6995G>T p.R2332L | Missense Mutation (SNP) | VAF 29/134 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.729); catalogued as COSV58129922; called by muse, mutect2, varscan2
- ACAP1 | c.957_958del p.C320Pfs*2 | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as rs1214380119; called by pindel, varscan2
- ACAP1 | c.2056G>A p.A686T | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1430504382, COSV50134290; called by muse, mutect2, varscan2
- ACCSL | c.901C>T p.L301F | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs768575115, COSV66580495, COSV66582484; called by muse, mutect2, varscan2
- ACHE | c.227G>A p.R76H | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.851); catalogued as rs200961647, COSV53815674; called by muse, mutect2, varscan2
- ACOT9 | c.301C>T p.R101* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV60537047; called by muse, mutect2, varscan2
- ACP1 | c.203G>A p.G68D | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.325); catalogued as COSV99681639; called by muse, mutect2, varscan2
- ACP7 | c.1316A>G p.*439Wext*33 | Nonstop Mutation (SNP) | VAF 61/214 reads (29%) | catalogued as COSV58698465; called by muse, mutect2, varscan2
- ACR | c.790del p.V264* | Frame Shift Del (DEL) | VAF 15/42 reads (36%) | catalogued as rs762191835; called by mutect2, pindel, varscan2
- ACSM1 | c.1217G>A p.S406N | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1567253839, COSV54636884; called by muse, mutect2, varscan2
- ACSM2A | c.1624A>G p.R542G (on ENST00000219054; = p.R463G on NM_001308169.2) | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752090939, COSV99525329; called by muse, mutect2, varscan2
- ACTA2 | c.950A>C p.K317T | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as COSV56515805; called by muse, mutect2, varscan2
- ACTG2 | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV61827712; called by muse, mutect2, varscan2
- ACTN2 | c.1181G>A p.R394Q | Missense Mutation (SNP) | VAF 27/105 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.833); catalogued as rs758358941, COSV63973008; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ACTN4 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0.161); catalogued as rs559700598; called by muse, mutect2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 54/146 reads (37%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM21 | c.769G>T p.G257* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | catalogued as COSV50789226; called by muse, mutect2, varscan2
- ADAMTS12 | c.1121G>A p.R374H | Missense Mutation (SNP) | VAF 32/292 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs1287419281, COSV61257410; called by muse, mutect2, varscan2
- ADAMTS18 | c.2085del p.F695Lfs*7 | Frame Shift Del (DEL) | VAF 41/169 reads (24%) | catalogued as rs772504358, COSV51414270; called by mutect2, varscan2
- ADAMTS19 | c.3497T>G p.L1166R | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50734547; called by muse, mutect2
- ADAMTS5 | c.2529A>T p.L843F | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.826); catalogued as COSV53176583; called by muse, mutect2
- ADAP1 | c.870C>T p.D290= | Splice Region (SNP) | VAF 22/103 reads (21%) | catalogued as rs746111308, COSV56211538; called by muse, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 40/160 reads (25%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRA1 | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.13); catalogued as rs112805112, COSV101658611; called by muse, varscan2
- ADGRA3 | c.3158T>G p.V1053G | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV51560827; called by muse, mutect2, varscan2
- ADGRB3 | c.3706A>T p.S1236C | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV53236627, COSV53237296; called by muse, mutect2, varscan2
- ADGRG3 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.025); catalogued as rs768416571, COSV59650397; called by muse, mutect2
- ADGRL1 | c.1699G>A p.A567T (on ENST00000340736 / NM_001008701.3; = p.A562T on NM_014921.5) | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs149895143; called by muse, mutect2, varscan2
- AHNAK2 | c.15163G>A p.G5055R | Missense Mutation (SNP) | VAF 54/199 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.3); catalogued as COSV60907193, COSV60909810, COSV60915841; called by muse, mutect2, varscan2
- AHR | c.928T>C p.Y310H | Missense Mutation (SNP) | VAF 36/217 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54122132; called by muse, mutect2, varscan2
- AIF1 | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61962218; called by muse, mutect2, varscan2
- AIM2 | c.959del p.N320Mfs*7 | Frame Shift Del (DEL) | VAF 78/354 reads (22%) | catalogued as rs752653022, COSV63698332; called by pindel, varscan2
- AK8 | c.36del p.E13Rfs*14 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs757477831; called by mutect2, pindel, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- AKR1B1 | c.806G>A p.R269H | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.014); catalogued as rs1380748552, COSV53646649; called by muse, varscan2
- AKR1B1 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.787); catalogued as rs145261078, COSV99605357; called by muse, varscan2
- ALAS2 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as rs863223900, COSV58188927; ClinVar: likely benign; called by muse, mutect2, varscan2
- ALDH3A1 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs545679214, COSV56734632; called by muse, mutect2, varscan2
- ALKBH6 | c.421C>T p.R141W (on ENST00000252984 / NM_001297701.2; = p.R169W on NM_032878.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/90 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.972); catalogued as rs765212006, COSV53324076; called by muse, mutect2, varscan2
- ALKBH8 | c.173G>A p.R58Q | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.996); catalogued as rs755059121, COSV52833710; called by muse, mutect2, varscan2
- ALMS1 | c.9889G>A p.V3297I | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs755789450, COSV52504589; called by muse, varscan2
- ALOX12 | c.1091C>T p.T364I | Missense Mutation (SNP) | VAF 67/226 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.151); catalogued as rs143493293, COSV52348898; called by muse, mutect2, varscan2
- ALOXE3 | c.2017G>A p.A673T | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.052); catalogued as COSV59074265; called by muse, mutect2, varscan2
- AMBRA1 | c.3470A>G p.E1157G (on ENST00000458649 / NM_001367468.1; = p.E1067G on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.755); catalogued as COSV54049947; called by muse, mutect2, varscan2
- AMER1 | c.2857C>A p.P953T | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.535); catalogued as COSV57656144, COSV57667941; called by muse, varscan2
- AMHR2 | c.1511G>A p.R504H | Missense Mutation (SNP) | VAF 44/141 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1412432973, COSV57685101; called by muse, mutect2, varscan2
- AMPH | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); catalogued as rs768225866, COSV100340628, COSV57735667, COSV57745382; called by muse, mutect2, varscan2
- ANK3 | c.9583G>T p.G3195C | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.95); catalogued as COSV55047932; called by muse, mutect2, varscan2
- ANKFN1 | c.1817G>A p.R606H | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.511); catalogued as rs749177645, COSV59442660; called by muse, varscan2
- ANKIB1 | c.437del p.N146Tfs*12 | Frame Shift Del (DEL) | VAF 10/45 reads (22%) | catalogued as rs201434379; called by mutect2, varscan2
- ANKMY1 | c.2298G>T p.K766N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.007); catalogued as COSV56030989; called by muse, mutect2, varscan2
- ANKRD44 | c.524G>A p.R175H | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.287); catalogued as rs762390824, COSV56550727; called by muse, mutect2, varscan2
- ANKRD50 | c.3173T>A p.I1058N | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.49); PolyPhen benign (0.148); catalogued as COSV72385235; called by muse, mutect2, varscan2
- ANKRD54 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 17/111 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.548); catalogued as rs144561541; called by muse, mutect2, varscan2
- ANKS1B | c.1006A>C p.K336Q | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.69); catalogued as COSV61338929; called by muse, mutect2, varscan2
- AP3D1 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs753212898, COSV61425304; called by muse, mutect2, varscan2
- APBB3 | c.533C>T p.A178V | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.185); catalogued as rs1288408788, COSV60051724; called by muse, mutect2, varscan2
- APC | c.1636A>G p.S546G | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as CD086009, COSV57330336; called by muse, mutect2
- ARAF | c.1686G>T p.Q562H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV51691597; called by muse, mutect2
- ARAP2 | c.3382G>A p.V1128I | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.526); catalogued as rs756759709, COSV58282863, COSV58283781; called by muse, mutect2, varscan2
- AREL1 | c.2390C>A p.P797H | Missense Mutation (SNP) | VAF 71/214 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62665696; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 49/191 reads (26%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARFGEF1 | c.716A>G p.H239R | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as COSV51603912; called by muse, mutect2, varscan2
- ARFGEF3 | c.1604G>A p.S535N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV52451767; called by muse, mutect2, varscan2
- ARHGAP33 | c.1340T>C p.L447P | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV50119972; called by muse, mutect2, varscan2
- ARHGAP39 | c.1064C>T p.P355L | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0.062); catalogued as rs1466140709; called by muse, varscan2
- ARHGAP4 | c.776A>G p.N259S | Missense Mutation (SNP) | VAF 31/215 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.176); catalogued as COSV63131029, COSV63134769; called by muse, mutect2, varscan2
- ARHGEF40 | c.3866G>A p.R1289H | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768330300, COSV53878795; called by muse, mutect2, varscan2
- ARID1A | c.3469G>T p.G1157* | Nonsense Mutation (SNP) | VAF 30/105 reads (29%) | catalogued as COSV61373219; called by muse, mutect2, varscan2
- ARID1A | c.5228C>T p.T1743M | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); catalogued as rs528936858, COSV61370863; ClinVar: likely benign; called by muse, mutect2, varscan2
- ARID1A | c.5548dup p.D1850Gfs*4 | Frame Shift Ins (INS) | VAF 34/137 reads (25%) | catalogued as rs758608743; called by mutect2, varscan2
- ARID5B | c.556C>T p.R186W | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54415710; called by muse, mutect2, varscan2
- ARPIN | c.136C>T p.R46W | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs756112595, COSV62589880; called by muse, mutect2, varscan2
- ARSI | c.1487A>G p.N496S | Missense Mutation (SNP) | VAF 10/162 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.408); catalogued as COSV60816851; called by muse, mutect2
- ASTN2 | c.661C>G p.L221V | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); catalogued as rs1252370323, COSV57757897; called by muse, mutect2, varscan2
- ATG14 | c.745C>T p.R249* | Nonsense Mutation (SNP) | VAF 14/174 reads (8%) | catalogued as COSV55955465, COSV55958773; called by muse, mutect2
- ATG2B | c.1975-2del p.X659_splice | Splice Site (DEL) | VAF 17/61 reads (28%) | catalogued as rs1182195036, COSV63427022; called by mutect2, pindel
- ATG7 | c.1167G>T p.K389N | Missense Mutation (SNP) | VAF 28/105 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.538); catalogued as COSV61611489; called by muse, mutect2, varscan2
- ATP10B | c.740T>A p.L247H | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58778007; called by mutect2, varscan2
- ATP13A5 | c.1426A>C p.M476L | Missense Mutation (SNP) | VAF 42/186 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs764391170, COSV60866801; called by muse, mutect2, varscan2
- ATP1A1 | c.3042C>T p.G1014= | Splice Region (SNP) | VAF 30/150 reads (20%) | catalogued as COSV55190117; called by muse, mutect2, varscan2
- ATP1A2 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs751210232, COSV63402662; called by muse, mutect2, varscan2
- ATP2C2 | c.2452A>G p.S818G | Missense Mutation (SNP) | VAF 19/199 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs777473870, COSV52293564; called by muse, mutect2, varscan2
- ATP6AP1 | c.631A>G p.K211E | Missense Mutation (SNP) | VAF 60/157 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV63895383; called by muse, mutect2, varscan2
- ATP6V1C2 | c.1217T>C p.L406P (on ENST00000272238 / NM_001039362.2; = p.L360P on NM_144583.4) | Missense Mutation (SNP) | VAF 10/169 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55349604; called by muse, mutect2
- ATP7A | c.583A>T p.K195* | Nonsense Mutation (SNP) | VAF 20/560 reads (4%) | catalogued as COSV58443607; called by muse, mutect2
- ATP8B3 | c.2567C>A p.S856Y | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.596); catalogued as COSV59540861; called by muse, mutect2
- ATP8B3 | c.1655T>C p.L552P | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV100034475; called by muse, mutect2
- ATP9A | c.1609A>G p.T537A | Missense Mutation (SNP) | VAF 14/192 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as COSV58764157; called by muse, mutect2
- ATXN2L | c.2152C>A p.H718N | Missense Mutation (SNP) | VAF 35/149 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV57366858; called by muse, mutect2, varscan2
- AUH | c.907A>G p.T303A | Missense Mutation (SNP) | VAF 28/140 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.391); catalogued as COSV57862014; called by muse, mutect2, varscan2
- AUTS2 | c.2782G>A p.A928T | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as rs1437864529, COSV61387629; called by muse, mutect2
- B4GALNT3 | c.1792G>T p.G598C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); catalogued as COSV56750492; called by muse, mutect2, varscan2
- B4GALT5 | c.826A>C p.S276R | Missense Mutation (SNP) | VAF 12/213 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV65492983; called by muse, mutect2
- B9D2 | c.484G>A p.G162S | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.37); PolyPhen benign (0.006); catalogued as rs760322583, COSV54683705; called by muse, mutect2, varscan2
- BBS9 | c.2183A>C p.K728T (on ENST00000242067 / NM_001348036.1; = p.K688T on NM_014451.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/283 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.068); catalogued as COSV54159295; called by muse, mutect2, varscan2
- BCAS1 | c.319A>G p.T107A | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs570638388, COSV65084365; called by muse, mutect2, varscan2
- BCL11A | c.1802G>A p.R601H (on ENST00000335712 / NM_001365609.1; = p.R635H on NM_018014.4) | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59625614; called by muse, mutect2, varscan2
- BCL9 | c.560A>G p.K187R | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as COSV52341913; called by muse, mutect2, varscan2
- BCLAF1 | c.563A>G p.K188R | Missense Mutation (SNP) | VAF 51/552 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.953); catalogued as COSV62140867; called by muse, mutect2
- BCORL1 | c.2762C>A p.P921H | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54391174, COSV99499036; called by muse, mutect2, varscan2
- BFAR | c.763dup p.Q255Pfs*7 | Frame Shift Ins (INS) | VAF 36/127 reads (28%) | catalogued as rs781267226; called by mutect2, varscan2
- BHLHE22 | c.427G>A p.G143S | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV100417794; called by muse, varscan2
- BICDL1 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778194508, COSV57492503; called by muse, mutect2, varscan2
- BIRC3 | c.772C>T p.R258C | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54815503; called by muse, mutect2, varscan2
- BMPR2 | c.1748del p.N583Tfs*44 | Frame Shift Del (DEL) | VAF 37/146 reads (25%) | catalogued as rs772920507, COSV65808737; called by mutect2, pindel, varscan2
- BOD1L1 | c.8087G>A p.G2696E | Missense Mutation (SNP) | VAF 60/359 reads (17%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as COSV50006881, COSV50088138; called by muse, mutect2, varscan2
- BOD1L1 | c.4856C>T p.A1619V | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV50007680, COSV50012487; called by muse, mutect2, varscan2
- BRAF | c.1328del p.P443Lfs*8 (on ENST00000288602 / NM_001374244.1; = p.P403Lfs*8 on NM_004333.6 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/101 reads (12%) | catalogued as COSV56263190; called by mutect2, pindel, varscan2
- BRD1 | c.2819A>G p.Y940C (on ENST00000216267 / NM_001349940.1; = p.Y1071C on NM_001304808.3) | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); catalogued as COSV53455346; called by muse, mutect2, varscan2
- BRD1 | c.1397T>C p.I466T | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV53455358; called by muse, mutect2, varscan2
- BRINP1 | c.2080C>T p.L694F | Missense Mutation (SNP) | VAF 10/189 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); catalogued as rs1339344037, COSV56294197; called by muse, mutect2
- BRWD3 | c.4928G>A p.S1643N | Missense Mutation (SNP) | VAF 79/483 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV64744971; called by muse, mutect2, varscan2
- BSN | c.10543C>A p.R3515S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.226); catalogued as COSV99608734; called by muse, mutect2, varscan2
- BTC | c.203G>T p.R68M | Missense Mutation (SNP) | VAF 82/326 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as COSV67547351; called by muse, mutect2, varscan2
- BTNL9 | c.1340G>A p.R447Q | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.459); catalogued as rs767405462, COSV59794331; called by muse, mutect2, varscan2
- BUD23 | c.626C>T p.S209L | Missense Mutation (SNP) | VAF 31/539 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.16); catalogued as rs1266528723, COSV56094350; called by muse, mutect2
- BVES | c.851G>A p.C284Y | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); catalogued as COSV58946898; called by muse, mutect2, varscan2
- C11orf49 | c.236del p.L79Yfs*18 | Frame Shift Del (DEL) | VAF 62/239 reads (26%) | catalogued as COSV99562457; called by mutect2, pindel, varscan2
- C11orf58 | c.163C>T p.R55C | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.235); catalogued as rs778301983, COSV57178185; called by muse, mutect2, varscan2
- C12orf40 | c.542T>G p.L181R | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.366); catalogued as COSV61130034, COSV61131094; called by muse, mutect2, varscan2
- C14orf39 | c.1670T>A p.F557Y | Missense Mutation (SNP) | VAF 64/270 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58780067; called by muse, varscan2
- C15orf39 | c.1421del p.P474Qfs*91 | Frame Shift Del (DEL) | VAF 23/81 reads (28%) | catalogued as COSV62298237; called by mutect2, pindel, varscan2
- C19orf57 | c.1535A>G p.Q512R | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.3); catalogued as COSV60967388; called by muse, mutect2, varscan2
- C1RL | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 22/51 reads (43%) | catalogued as COSV56923820; called by muse, mutect2, varscan2
- C1orf94 | c.580A>G p.I194V (on ENST00000488417 / NM_001134734.2; = p.I4V on NM_032884.5) | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV64913270; called by muse, mutect2, varscan2
- C5 | c.599C>T p.T200M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.068); catalogued as rs767070451, COSV56324677; called by muse, mutect2, varscan2
- C5orf22 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57597753; called by muse, mutect2, varscan2
- C6 | c.178T>A p.F60I | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.124); catalogued as COSV54706654; called by muse, mutect2, varscan2
- C9 | c.1522A>G p.R508G | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as COSV54674923; called by muse, mutect2, varscan2
- CACFD1 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 50/239 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.217); catalogued as rs782678068, COSV52469040; called by muse, varscan2
- CACFD1 | c.175G>A p.A59T | Missense Mutation (SNP) | VAF 30/200 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.28); catalogued as rs781984451, COSV52469059; called by muse, varscan2
- CACNA1D | c.3218G>A p.R1073H (on ENST00000350061 / NM_001128840.3; = p.R1093H on NM_000720.4) | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.013); catalogued as rs758204752, COSV55440211, COSV55466951; called by muse, mutect2, varscan2
- CACNA1G | c.712C>T p.R238W | Missense Mutation (SNP) | VAF 27/71 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61720249; called by muse, mutect2, varscan2
- CACNA2D2 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 73/260 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.04); catalogued as rs201610016, COSV56561218; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CACNG3 | c.742T>C p.S248P | Missense Mutation (SNP) | VAF 12/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV50064623; called by muse, mutect2
- CACNG7 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV55813346, COSV55816386; called by muse, mutect2, varscan2
- CALCR | c.1331C>T p.A444V (on ENST00000649521 / NM_001164737.2; = p.A428V on NM_001742.4) | Missense Mutation (SNP) | VAF 35/160 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.015); catalogued as COSV64006465; called by muse, mutect2, varscan2
- CALD1 | c.2074G>A p.A692T (on ENST00000361675 / NM_033138.4; = p.A437T on NM_004342.7) | Missense Mutation (SNP) | VAF 11/81 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.223); catalogued as rs756255320, COSV62649535; called by muse, mutect2
- CAMSAP1 | c.3727G>C p.A1243P | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.623); catalogued as COSV56718764; called by muse, mutect2, varscan2
- CAMTA1 | c.3403C>T p.R1135W | Missense Mutation (SNP) | VAF 47/173 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57886124; called by muse, mutect2, varscan2
- CAND2 | c.1942C>T p.P648S (on ENST00000456430 / NM_001162499.2; = p.P555S on NM_012298.3) | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.109); catalogued as COSV55987572; called by muse, mutect2, varscan2
- CARD11 | c.1663del p.R555Gfs*45 | Frame Shift Del (DEL) | VAF 10/80 reads (13%) | catalogued as rs762770988, COSV62756627; called by mutect2, pindel, varscan2
- CARD11 | c.839A>C p.N280T | Missense Mutation (SNP) | VAF 54/254 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV67797499; called by muse, mutect2, varscan2
- CARNS1 | c.1390G>A p.G464S | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.694); catalogued as rs745605718, COSV57048100; called by muse, mutect2, varscan2
- CASP8AP2 | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 140/348 reads (40%) | SIFT tolerated (0.13); PolyPhen benign (0.439); catalogued as rs773140007, COSV52745634, COSV52749843; called by muse, mutect2, varscan2
- CASP8AP2 | c.3390del p.K1130Nfs*6 | Frame Shift Del (DEL) | VAF 7/23 reads (30%) | catalogued as rs768812342; called by mutect2, varscan2
- CATSPER3 | c.482A>G p.Q161R | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV50945354; called by muse, mutect2, varscan2
- CBLL2 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 26/103 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV60368352, COSV60369991; called by muse, mutect2, varscan2
- CBX5 | c.317del p.K106Rfs*31 | Frame Shift Del (DEL) | VAF 114/350 reads (33%) | catalogued as rs780649799; called by mutect2, varscan2
- CCDC149 | c.265-1G>T p.X89_splice | Splice Site (SNP) | VAF 43/160 reads (27%) | catalogued as COSV60877203; called by muse, mutect2, varscan2
- CCDC178 | c.1895del p.K632Rfs*9 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as COSV55780370; called by mutect2, varscan2
- CCDC185 | c.1129C>T p.R377W | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as rs533876891, COSV64820222; called by muse, mutect2
- CCDC186 | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 39/178 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.455); catalogued as rs768708509, COSV100991098, COSV65160779; called by muse, mutect2, varscan2
- CCDC43 | c.646del p.R216Gfs*20 | Frame Shift Del (DEL) | VAF 8/47 reads (17%) | catalogued as rs751135235; called by mutect2, varscan2
- CCDC73 | c.2447A>T p.N816I | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.155); catalogued as rs749684778, COSV58796283; called by muse, mutect2, varscan2
- CCDC74A | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as rs146378866; called by muse, mutect2, varscan2
- CCDC88B | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 15/62 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746367594, COSV57265208; called by muse, mutect2, varscan2
- CCDC89 | c.398A>C p.H133P | Missense Mutation (SNP) | VAF 46/181 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as COSV57033641; called by muse, mutect2, varscan2
- CCND3 | c.722G>A p.R241Q | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.71); catalogued as rs767328984, COSV57828001; called by muse, mutect2, varscan2
- CCNE2 | c.195del p.I66Sfs*14 | Frame Shift Del (DEL) | VAF 22/120 reads (18%) | catalogued as rs1563684829; called by mutect2, pindel, varscan2
- CCPG1 | c.739G>C p.V247L | Missense Mutation (SNP) | VAF 18/136 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.037); catalogued as COSV60524364; called by muse, mutect2, varscan2
- CD247 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs751145956, COSV62977281; called by muse, mutect2, varscan2
- CD274 | c.869C>T p.T290M | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.791); catalogued as rs369350813; called by muse, mutect2, varscan2
- CD5 | c.848G>A p.S283N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.018); catalogued as COSV61717957; called by muse, mutect2, varscan2
- CD82 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs574662941, COSV57034164, COSV99907558; called by muse, mutect2, varscan2
- CD8A | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.67); PolyPhen possibly damaging (0.646); catalogued as rs1165098264, COSV52156630, COSV52157473; called by muse, mutect2, varscan2
- CDC23 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as COSV67509425; called by muse, mutect2, varscan2
- CDC40 | c.588G>T p.W196C | Missense Mutation (SNP) | VAF 31/148 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57008210; called by muse, mutect2, varscan2
- CDC5L | c.278C>T p.A93V | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV65175531; called by muse, mutect2
- CDH10 | c.1528A>C p.I510L | Missense Mutation (SNP) | VAF 39/228 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.113); catalogued as COSV52573296; called by muse, mutect2, varscan2
- CDH11 | c.518A>C p.N173T | Missense Mutation (SNP) | VAF 22/246 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.34); catalogued as COSV51753771; called by muse, mutect2
- CDH24 | c.845G>A p.R282Q | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs764282796, COSV52974166; called by muse, mutect2, varscan2
- CDH8 | c.1736G>C p.S579T | Missense Mutation (SNP) | VAF 20/87 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0.05); catalogued as COSV54853246; called by muse, mutect2, varscan2
- CDK5RAP2 | c.2974G>A p.A992T | Missense Mutation (SNP) | VAF 69/330 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV62572666; called by muse, mutect2, varscan2
- CDKN2A | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs755927351, COSV58687466; called by muse, mutect2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs763090473; called by mutect2, varscan2
- CEMIP2 | c.2288C>T p.A763V | Missense Mutation (SNP) | VAF 52/223 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as COSV65485913; called by muse, mutect2, varscan2
- CEP20 | c.53del p.K18Rfs*4 | Frame Shift Del (DEL) | VAF 24/110 reads (22%) | catalogued as rs746479678; called by mutect2, pindel, varscan2
- CEP250 | c.6506G>A p.W2169* | Nonsense Mutation (SNP) | VAF 28/89 reads (31%) | catalogued as COSV100698973; called by muse, mutect2, varscan2
- CFAP61 | c.1601A>G p.Y534C | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55621757, COSV99843714; called by muse, mutect2, varscan2
- CHD6 | c.6013G>C p.E2005Q | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.177); catalogued as rs879691040, COSV64688777; called by muse, mutect2, varscan2
- CHD7 | c.3346A>G p.K1116E | Missense Mutation (SNP) | VAF 30/213 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV71107649; called by muse, mutect2, varscan2
- CHD7 | c.5816G>A p.R1939Q | Missense Mutation (SNP) | VAF 33/152 reads (22%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as rs1024797402, COSV71107652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHD9 | c.808T>A p.F270I | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV68297283; called by muse, mutect2
- CHEK2 | c.1589A>G p.Q530R (on ENST00000382580 / NM_001005735.2; = p.Q487R on NM_007194.4) | Missense Mutation (SNP) | VAF 25/378 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.033); catalogued as COSV60417016; called by muse, mutect2
- CHMP1B | c.477G>T p.E159D | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.571); catalogued as COSV52324342; called by muse, mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 24/65 reads (37%) | catalogued as rs751548647; called by mutect2, varscan2
- CHRNA1 | c.1295A>C p.K432T (on ENST00000261007 / NM_001039523.3; = p.K407T on NM_000079.4) | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV53681940, COSV53681990; called by muse, mutect2, varscan2
- CHRNA10 | c.988C>T p.R330C | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs199780107, COSV51703219; called by muse, mutect2, varscan2
- CHRNA6 | c.863T>C p.V288A | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs373608967; called by muse, mutect2, varscan2
- CHST13 | c.608G>A p.R203H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.883); catalogued as COSV60041590; called by muse, mutect2
- CHTOP | c.560G>A p.R187Q | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT tolerated (0.35); PolyPhen benign (0.113); catalogued as rs747313687, COSV64154924; called by muse, varscan2
- CIPC | c.155T>C p.L52P | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.346); catalogued as COSV62376754; called by muse, mutect2, varscan2
- CLCA1 | c.2656A>G p.N886D | Missense Mutation (SNP) | VAF 50/194 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748700845, COSV52325759; called by muse, mutect2, varscan2
- CLCA4 | c.218del p.F73Sfs*7 | Frame Shift Del (DEL) | VAF 28/140 reads (20%) | catalogued as rs745822656; called by mutect2, varscan2
- CLCN5 | c.148A>G p.S50G | Missense Mutation (SNP) | VAF 37/156 reads (24%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV56582753; called by muse, mutect2, varscan2
- CLCNKB | c.1726G>A p.V576M | Missense Mutation (SNP) | VAF 20/70 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as rs571234167, COSV65152871; called by muse, mutect2, varscan2
- CLDN11 | c.247G>A p.A83T | Missense Mutation (SNP) | VAF 72/331 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs746584633, COSV50355135; called by muse, mutect2, varscan2
- CLEC4A | c.610G>A p.V204I | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs373496736, COSV99983588; called by muse, mutect2
- CLTCL1 | c.349A>G p.N117D | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.029); catalogued as COSV54226327; called by muse, mutect2, varscan2
- CLU | c.187dup p.T63Nfs*25 | Frame Shift Ins (INS) | VAF 63/340 reads (19%) | catalogued as rs747368775; called by mutect2, pindel, varscan2
- CNGA4 | c.1564G>A p.A522T | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs149747380; called by muse, mutect2, varscan2
- CNKSR1 | c.1664C>T p.A555V (on ENST00000374253 / NM_001297647.2; = p.A548V on NM_006314.3) | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV58792474; called by muse, mutect2, varscan2
- CNKSR2 | c.3095C>T p.T1032M | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV65278839; called by muse, mutect2, varscan2
- CNOT3 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs1316264758, COSV55360963; called by muse, mutect2, varscan2
- CNTLN | c.3922del p.M1308* | Frame Shift Del (DEL) | VAF 45/266 reads (17%) | catalogued as rs761011518, COSV99078405; called by mutect2, pindel, varscan2
- COASY | c.1317A>G p.I439M | Missense Mutation (SNP) | VAF 42/274 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV55897840; called by muse, mutect2, varscan2
- COBL | c.2390C>T p.P797L | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV54340374; called by muse, mutect2, varscan2
- COBLL1 | c.2834del p.L945Cfs*12 (on ENST00000392717; = p.L907Cfs*12 on NM_014900.5) | Frame Shift Del (DEL) | VAF 38/72 reads (53%) | catalogued as rs374805044; called by mutect2, varscan2
- COL18A1 | c.3097G>A p.G1033R (on ENST00000359759 / NM_130444.3; = p.G798R on NM_030582.4) | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs368967629; called by muse, mutect2, varscan2
- COL22A1 | c.1016C>T p.A339V | Missense Mutation (SNP) | VAF 13/275 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.536); catalogued as COSV57327495; called by muse, mutect2
- COL22A1 | c.811C>T p.R271W | Missense Mutation (SNP) | VAF 17/113 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs141938188, COSV57333337; called by muse, mutect2, varscan2
- COL23A1 | c.887C>T p.A296V | Missense Mutation (SNP) | VAF 66/233 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.246); catalogued as rs369107371; called by muse, mutect2, varscan2
- COL25A1 | c.76C>T p.H26Y | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.68); PolyPhen benign (0.007); catalogued as COSV67647478; called by muse, mutect2, varscan2
- COL27A1 | c.4676G>C p.G1559A | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61921749, COSV61922648; called by muse, mutect2, varscan2
- COL2A1 | c.310-2A>G p.X104_splice | Splice Site (SNP) | VAF 32/99 reads (32%) | catalogued as COSV61528614; called by muse, mutect2, varscan2
- COL4A1 | c.4936A>G p.T1646A | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT tolerated (0.57); PolyPhen benign (0.048); catalogued as COSV65422508; called by muse, mutect2, varscan2
- COL6A2 | c.2180C>T p.A727V | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.431); catalogued as rs1408523098, COSV56000808; called by muse, mutect2
- COL8A2 | c.684del p.G229Afs*8 | Frame Shift Del (DEL) | VAF 11/33 reads (33%) | catalogued as rs769991029; called by mutect2, pindel, varscan2
- COLEC12 | c.253G>T p.A85S | Missense Mutation (SNP) | VAF 29/93 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.025); catalogued as COSV68369104, COSV68369120; called by muse, mutect2, varscan2
- CPEB4 | c.2159G>A p.R720H | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54170163; called by muse, mutect2, varscan2
- CPLANE2 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs370908519; called by muse, mutect2, varscan2
- CPN2 | c.131C>T p.P44L | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs982803111, COSV60469721; called by muse, mutect2, varscan2
- CPSF1 | c.1735C>T p.R579W | Missense Mutation (SNP) | VAF 62/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1554865023, COSV62939224; called by muse, mutect2, varscan2
- CREB3L1 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs777788054, COSV55830529; called by muse, mutect2, varscan2
- CREBBP | c.3250del p.I1084Sfs*15 | Frame Shift Del (DEL) | VAF 61/253 reads (24%) | catalogued as rs1378599948; called by mutect2, pindel, varscan2
- CRMP1 | c.1169A>C p.K390T | Missense Mutation (SNP) | VAF 43/192 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV61478641; called by muse, mutect2, varscan2
- CRTC2 | c.1811A>C p.N604T | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.245); catalogued as COSV57841390; called by muse, mutect2, varscan2
- CRYBG2 | c.1178del p.K393Rfs*16 | Frame Shift Del (DEL) | VAF 14/48 reads (29%) | catalogued as rs747248693; called by mutect2, varscan2
- CSAD | c.980G>A p.R327H (on ENST00000444623 / NM_001244705.2; = p.R354H on NM_015989.5) | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.009); catalogued as rs368428943; called by muse, mutect2, varscan2
- CSMD1 | c.10144A>G p.T3382A (on ENST00000520002; = p.T3381A on NM_033225.6) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs950974690, COSV59292844; called by muse, mutect2
- CSMD1 | c.3572T>C p.L1191P (on ENST00000520002; = p.L1190P on NM_033225.6) | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59292877; called by muse, mutect2, varscan2
- CSMD3 | c.2497G>A p.E833K (on ENST00000297405 / NM_001363185.1; = p.E729K on NM_052900.3) | Missense Mutation (SNP) | VAF 17/148 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52122841; called by muse, mutect2, varscan2
- CSPG4 | c.4879del p.Q1627Sfs*2 | Frame Shift Del (DEL) | VAF 19/67 reads (28%) | catalogued as rs1332907606; called by mutect2, pindel, varscan2
- CSTF2T | c.1209G>T p.R403S | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); catalogued as COSV58656048; called by muse, mutect2
- CT55 | c.125T>C p.V42A | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.033); catalogued as COSV52277237; called by muse, mutect2, varscan2
- CTBS | c.235A>G p.T79A | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55361514; called by muse, mutect2
- CTC1 | c.787G>A p.V263M | Missense Mutation (SNP) | VAF 22/107 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1010062693, COSV59852425; called by muse, mutect2, varscan2
- CTNNA1 | c.1479del p.K493Nfs*31 | Frame Shift Del (DEL) | VAF 114/429 reads (27%) | catalogued as COSV57081469; called by mutect2, varscan2
- CTNNA1 | c.2366A>G p.Q789R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57070626; called by muse, mutect2, varscan2
- CTNNA2 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.227); catalogued as rs1216702402, COSV63552128; called by muse, mutect2, varscan2
- CTNNBL1 | c.1442T>A p.F481Y | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV63744035; called by muse, mutect2, varscan2
- CTSE | c.911A>G p.N304S (on ENST00000360218; = p.N299S on NM_001910.4) | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as COSV63059976; called by muse, mutect2, varscan2
- CUBN | c.2593A>C p.S865R | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.2); PolyPhen benign (0.295); catalogued as COSV64709662; called by muse, mutect2, varscan2
- CUX1 | c.2188C>T p.Q730* | Nonsense Mutation (SNP) | VAF 82/371 reads (22%) | catalogued as COSV52893190; called by muse, mutect2, varscan2
- CX3CL1 | c.815C>T p.T272M | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.182); catalogued as rs201467674, COSV50055436; called by muse, mutect2, varscan2
- CXorf56 | c.462G>T p.E154D (on ENST00000536133 / NM_001170570.2; = p.E168D on NM_022101.4) | Missense Mutation (SNP) | VAF 31/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57437804; called by muse, mutect2, varscan2
- CYTH2 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs868252335, COSV57308891; called by muse, mutect2, varscan2
- DAP3 | c.1144T>C p.F382L | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as rs1431035105, COSV58019539; called by muse, mutect2, varscan2
- DAPK1 | c.1538C>T p.T513M | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs778729228, COSV63785136; called by muse, mutect2, varscan2
- DBF4B | c.962G>T p.R321L | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.468); catalogued as COSV59259336; called by muse, mutect2, varscan2
- DCC | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.849); catalogued as rs962808767, COSV59089734; called by muse, mutect2, varscan2
- DCHS1 | c.1904G>T p.S635I | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55031885; called by muse, mutect2, varscan2
- DCLK1 | c.674A>C p.K225T | Missense Mutation (SNP) | VAF 32/222 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55175885, COSV55179596; called by muse, mutect2, varscan2
- DDI1 | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV56370406; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 37/126 reads (29%) | catalogued as rs766714372; called by mutect2, varscan2
- DEAF1 | c.776C>T p.A259V | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as rs1564949612, COSV58605718; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DECR1 | c.137C>A p.P46H | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV55167278; called by muse, mutect2, varscan2
- DEFB110 | c.89A>G p.D30G | Missense Mutation (SNP) | VAF 34/294 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV64484360; called by muse, mutect2, varscan2
- DENND2A | c.2455G>A p.G819R | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746618150, COSV52048627; called by muse, mutect2, varscan2
- DENND4B | c.1039C>T p.R347C | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.733); catalogued as rs749288468, COSV63407564; called by muse, mutect2, varscan2
- DEPDC7 | c.628C>T p.R210C (on ENST00000241051 / NM_001077242.2; = p.R201C on NM_139160.2) | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749658035, COSV53806174, COSV53807601; called by muse, mutect2, varscan2
- DGKH | c.1956G>C p.Q652H | Missense Mutation (SNP) | VAF 51/233 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV54928751; called by muse, mutect2, varscan2
- DHX15 | c.1741T>C p.Y581H | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61025949; called by muse, mutect2
- DIRAS2 | c.97C>T p.R33W | Missense Mutation (SNP) | VAF 76/341 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); catalogued as rs779203948, COSV65370071; called by muse, mutect2, varscan2
- DLC1 | c.3833C>G p.A1278G (on ENST00000276297 / NM_001348081.2; = p.A841G on NM_006094.5) | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as COSV52293558; called by muse, mutect2
- DLEC1 | c.5248A>G p.M1750V | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57171206; called by muse, mutect2, varscan2
- DLG2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 51/157 reads (32%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs150156552, COSV54627336; called by muse, mutect2, varscan2
- DMD | c.8851C>T p.R2951C | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.54); catalogued as rs760516307, COSV58896066; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DMXL1 | c.209G>A p.G70D | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV60706340; called by muse, mutect2, varscan2
- DNA2 | c.2335del p.S779Hfs*6 | Frame Shift Del (DEL) | VAF 11/36 reads (31%) | catalogued as rs745893364; called by mutect2, varscan2
- DNAAF3 | c.265del p.R89Dfs*4 (on ENST00000524407 / NM_001256715.2; = p.R136Dfs*4 on NM_178837.4) | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | catalogued as CM122506; called by mutect2, pindel, varscan2
- DNAH1 | c.1532C>T p.T511M | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as rs200623391, COSV70227029; called by mutect2, varscan2
- DNAH10 | c.11637G>T p.L3879F (on ENST00000409039; = p.L3818F on NM_207437.3) | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0.381); catalogued as COSV68989383; called by muse, mutect2, varscan2
- DNAH10 | c.13415A>C p.K4472T (on ENST00000409039; = p.K4411T on NM_207437.3) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.187); catalogued as COSV53018848; called by muse, mutect2, varscan2
- DNAH17 | c.12989C>T p.S4330L | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs149945771; called by muse, mutect2
- DNAH3 | c.4811G>A p.R1604H | Missense Mutation (SNP) | VAF 13/63 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs964016861, COSV54508424; called by muse, mutect2, varscan2
- DNAH6 | c.1534A>G p.M512V | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as COSV99407087; called by muse, mutect2, varscan2
- DNAJB13 | c.578G>A p.R193H | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as rs376516482; called by mutect2, varscan2
- DNAJC10 | c.950G>C p.G317A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51136243; called by muse, mutect2, varscan2
- DNAJC11 | c.1254-2A>G p.X418_splice | Splice Site (SNP) | VAF 7/64 reads (11%) | catalogued as COSV50010626; called by muse, mutect2, varscan2
- DNAJC4 | c.381del p.N128Tfs*11 | Frame Shift Del (DEL) | VAF 10/53 reads (19%) | catalogued as rs1000579773; called by mutect2, pindel, varscan2
- DNMT1 | c.3419G>A p.R1140Q | Missense Mutation (SNP) | VAF 43/145 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as rs767421908, COSV61577175; called by muse, mutect2, varscan2
- DNMT1 | c.2483T>C p.I828T | Missense Mutation (SNP) | VAF 157/567 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV61577179; called by muse, mutect2, varscan2
- DOCK10 | c.1539A>C p.K513N | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51355768; called by muse, mutect2
- DOCK5 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV52397321; called by muse, mutect2, varscan2
- DOCK8 | c.2162T>C p.V721A | Missense Mutation (SNP) | VAF 55/286 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV66618447; called by muse, varscan2
- DOK1 | c.35dup p.L12Ffs*33 | Frame Shift Ins (INS) | VAF 11/38 reads (29%) | catalogued as rs759252474; called by mutect2, varscan2
- DPH2 | c.1393G>T p.G465C | Missense Mutation (SNP) | VAF 21/111 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52542765; called by muse, mutect2, varscan2
- DPYD | c.547T>C p.S183P | Missense Mutation (SNP) | VAF 91/332 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64592673; called by muse, mutect2, varscan2
- DRP2 | c.1586G>A p.R529H | Missense Mutation (SNP) | VAF 58/203 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs758782031, COSV65809493; called by muse, mutect2, varscan2
- DSCAML1 | c.1345A>G p.T449A (on ENST00000321322; = p.T389A on NM_020693.4) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0.389); catalogued as COSV58384104; called by muse, mutect2
- DSEL | c.1414A>C p.S472R | Missense Mutation (SNP) | VAF 12/122 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100025940, COSV59489055; called by muse, mutect2
- DST | c.13182del p.V4395Ffs*13 (on ENST00000361203 / NM_001374722.1; = p.V1983Ffs*13 on NM_015548.5) | Frame Shift Del (DEL) | VAF 48/146 reads (33%) | catalogued as rs1190969813; called by mutect2, pindel, varscan2
- DSTYK | c.2461T>C p.F821L | Missense Mutation (SNP) | VAF 35/139 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.313); catalogued as COSV65685686; called by muse, mutect2, varscan2
- DTNA | c.519A>C p.E173D | Missense Mutation (SNP) | VAF 30/136 reads (22%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.976); catalogued as COSV51994038; called by muse, mutect2, varscan2
- DTX4 | c.970T>G p.S324A | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.089); catalogued as COSV57088993; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.550A>G p.T184A | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.717); catalogued as COSV50051129; called by muse, mutect2, varscan2
- DYNC2I1 | c.1580del p.N527Ifs*23 | Frame Shift Del (DEL) | VAF 32/148 reads (22%) | catalogued as rs751377941; called by mutect2, varscan2
- EBF2 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.07); catalogued as COSV68776558; called by muse, varscan2
- EDC4 | c.3329T>C p.M1110T | Missense Mutation (SNP) | VAF 23/68 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV59302115; called by muse, mutect2, varscan2
- EDRF1 | c.3611C>T p.A1204V (on ENST00000356792 / NM_001202438.2; = p.A1170V on NM_015608.2) | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV61762699; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2246C>T p.A749V | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.142); catalogued as COSV62567004; called by muse, mutect2
- EFCAB1 | c.8G>A p.R3H | Missense Mutation (SNP) | VAF 47/200 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs753689165, COSV50617909; called by muse, mutect2, varscan2
- EFCAB13 | c.1847C>G p.T616R | Missense Mutation (SNP) | VAF 10/111 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as COSV58946308; called by muse, mutect2
- EGF | c.1553A>T p.D518V | Missense Mutation (SNP) | VAF 23/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54476606; called by muse, mutect2
- EIF2AK1 | c.592del p.I198Sfs*2 | Frame Shift Del (DEL) | VAF 6/34 reads (18%) | catalogued as rs767715156, COSV104389006; called by mutect2, varscan2
- EIF2AK3 | c.3178C>A p.P1060T | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.46); PolyPhen benign (0.406); catalogued as COSV57545634; called by muse, mutect2, varscan2
- EIF2B1 | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.464); catalogued as rs755256108, COSV71193843; called by muse, mutect2, varscan2
- EIF2S2 | c.628G>A p.V210I | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.959); catalogued as rs760616209, COSV100894974; called by muse, mutect2, varscan2
- EIF4ENIF1 | c.1997G>A p.R666Q | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.994); catalogued as COSV57514976; called by muse, mutect2, varscan2
- ELF2 | c.1718C>T p.A573V (on ENST00000379550 / NM_001331036.2; = p.A513V on NM_006874.4) | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as rs781524405, COSV55492114; called by muse, mutect2, varscan2
- ELFN2 | c.2323C>T p.P775S | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV68744015; called by muse, mutect2, varscan2
- ELL3 | c.1124A>G p.Y375C | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55855034; called by muse, mutect2
- ELMO1 | c.569A>C p.K190T | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.6); PolyPhen benign (0.06); catalogued as COSV100163273, COSV100164764; called by muse, mutect2, varscan2
- ELOA | c.1394del p.N465Mfs*19 | Frame Shift Del (DEL) | VAF 61/247 reads (25%) | catalogued as rs766700925; called by mutect2, varscan2
- EMILIN1 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs770735343, COSV53153681; called by muse, mutect2, varscan2
- EML2 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 85/261 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as COSV55597983, COSV55603814; called by muse, mutect2, varscan2
- EML2 | c.77G>A p.R26K | Missense Mutation (SNP) | VAF 32/137 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.371); catalogued as COSV55598001; called by muse, mutect2, varscan2
- EML3 | c.1209T>C p.S403= | Splice Region (SNP) | VAF 34/96 reads (35%) | catalogued as COSV53881651; called by muse, mutect2, varscan2
- EML5 | c.4843G>A p.G1615R (on ENST00000380664; = p.G1623R on NM_183387.3) | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61342782; called by muse, mutect2, varscan2
- EML5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 47/202 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.146); catalogued as rs374179617; called by muse, mutect2, varscan2
- ENG | c.771del p.Y258Tfs*101 | Frame Shift Del (DEL) | VAF 9/60 reads (15%) | catalogued as CD075380; called by mutect2, pindel, varscan2
- EP400 | c.3271A>T p.I1091F | Missense Mutation (SNP) | VAF 34/139 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV57765333; called by muse, mutect2, varscan2
- EPAS1 | c.809A>C p.E270A | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV55384810; called by muse, mutect2
- EPG5 | c.1201C>T p.L401F | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as rs1411427830, COSV56345977; called by muse, mutect2, varscan2
- EPHA10 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 30/71 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60402354; called by muse, mutect2, varscan2
- EPHB1 | c.2284G>A p.D762N | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67653779; called by muse, mutect2, varscan2
- EPHB1 | c.2593C>T p.R865W | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758204492, COSV67653431; called by muse, mutect2, varscan2
- EPN2 | c.1026del p.S343Afs*108 | Frame Shift Del (DEL) | VAF 31/139 reads (22%) | catalogued as COSV100127541; called by mutect2, pindel, varscan2
- EPRS1 | c.3060del p.E1021Kfs*17 | Frame Shift Del (DEL) | VAF 28/134 reads (21%) | catalogued as rs1394740497; called by mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 16/87 reads (18%) | catalogued as rs768793415; called by mutect2, varscan2
- ERBB3 | c.917C>A p.P306H | Missense Mutation (SNP) | VAF 112/414 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57247209, COSV57255329; called by muse, mutect2, varscan2
- ERCC6L2 | c.1955A>G p.H652R | Missense Mutation (SNP) | VAF 42/174 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as COSV56628812; called by muse, mutect2, varscan2
- ERMP1 | c.1951del p.T651Pfs*3 | Frame Shift Del (DEL) | VAF 20/99 reads (20%) | catalogued as rs753821453; called by mutect2, varscan2
- ERN2 | c.1910A>G p.D637G | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55621013; called by muse, mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 22/108 reads (20%) | catalogued as rs775950025; called by mutect2, varscan2
- ESX1 | c.149A>G p.K50R | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.007); catalogued as COSV65424023; called by muse, mutect2
- ESYT2 | c.2404A>G p.K802E (on ENST00000613624; = p.K726E on NM_020728.3) | Missense Mutation (SNP) | VAF 25/190 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as COSV51748523; called by muse, mutect2, varscan2
- ETFB | c.656C>T p.T219I | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.051); catalogued as COSV58535308; called by muse, mutect2, varscan2
- ETV1 | c.414del p.T139Hfs*116 | Frame Shift Del (DEL) | VAF 32/185 reads (17%) | catalogued as COSV54136078; called by mutect2, pindel, varscan2
- EVC | c.1148A>G p.E383G | Missense Mutation (SNP) | VAF 34/144 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); catalogued as rs1201423468, COSV53830017; called by muse, varscan2
- EVI2A | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.823); catalogued as COSV55985657; called by muse, mutect2, varscan2
- EVI5 | c.648del p.F216Lfs*15 | Frame Shift Del (DEL) | VAF 13/119 reads (11%) | catalogued as rs1453325274; called by mutect2, pindel, varscan2
- EVI5L | c.622A>G p.M208V | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV54484245; called by muse, mutect2, varscan2
- EXOC3L4 | c.1466+2T>C p.X489_splice | Splice Site (SNP) | VAF 8/38 reads (21%) | catalogued as rs780030946, COSV66295357; called by muse, mutect2
- EXTL3 | c.1841T>C p.F614S | Missense Mutation (SNP) | VAF 52/247 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.04); catalogued as COSV55037122; called by muse, mutect2, varscan2
- F8 | c.6882del p.Q2295Rfs*5 | Frame Shift Del (DEL) | VAF 85/506 reads (17%) | catalogued as CD015897, CD032115; called by mutect2, pindel, varscan2
- FAAH2 | c.1251G>T p.K417N | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.062); catalogued as rs748317673, COSV66505989; called by muse, mutect2, varscan2
- FAM120A | c.2555G>T p.S852I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.062); catalogued as COSV52902458; called by muse, mutect2, varscan2
- FAM122C | c.28T>C p.F10L | Missense Mutation (SNP) | VAF 24/330 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV66194722; called by muse, mutect2
- FAM131B | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 74/322 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.013); catalogued as rs537589173, COSV58368047; called by muse, varscan2
- FAM149A | c.1778G>A p.R593Q (on ENST00000356371 / NM_001367768.2; = p.R302Q on NM_015398.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.522); catalogued as rs139445329; called by muse, mutect2, varscan2
- FAM151A | c.351del p.T118Lfs*43 | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs749953492; called by mutect2, pindel
- FAM169A | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65846146; called by muse, mutect2, varscan2
- FAM171A1 | c.1613A>G p.E538G | Missense Mutation (SNP) | VAF 66/281 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.13); catalogued as COSV65314168; called by muse, mutect2, varscan2
- FAM181B | c.175G>A p.V59M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as COSV61300417; called by muse, mutect2
- FAM184A | c.3044A>C p.K1015T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1302705387, COSV58852333; called by muse, mutect2, varscan2
- FAM47C | c.1787del p.P596Rfs*229 | Frame Shift Del (DEL) | VAF 28/137 reads (20%) | catalogued as COSV63724780; called by pindel, varscan2
- FAM71B | c.443G>A p.R148H | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780542907, COSV57227920; called by muse, mutect2, varscan2
- FAM83H | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1488668089, COSV66353569; called by muse, mutect2
- FANCB | c.91A>C p.N31H | Missense Mutation (SNP) | VAF 10/214 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.444); catalogued as COSV60759069; called by muse, mutect2
- FASTK | c.1451G>A p.R484H | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs1563373270, COSV52539413; called by muse, mutect2, varscan2
- FAT2 | c.1731G>A p.W577* | Nonsense Mutation (SNP) | VAF 45/152 reads (30%) | catalogued as rs202003550; called by muse, varscan2
- FAT2 | c.211T>C p.Y71H | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55815092; called by muse, mutect2
- FAT3 | c.11008C>T p.R3670W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1186961349, COSV53085015; called by muse, mutect2, varscan2
- FBN1 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 129/526 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV57311356, COSV57323668; called by muse, mutect2, varscan2
- FBN3 | c.2656G>A p.V886I | Missense Mutation (SNP) | VAF 16/78 reads (21%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs758594630, COSV54455168; called by muse, mutect2, varscan2
- FBXL17 | c.1208G>A p.G403D | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62849680; called by muse, mutect2, varscan2
- FBXL6 | c.1396A>G p.S466G | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs61747069; called by muse, mutect2
- FBXL6 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 17/80 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs781950982, COSV57351043; called by muse, mutect2, varscan2
- FBXL7 | c.1124G>A p.C375Y | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61642460; called by muse, mutect2, varscan2
- FBXO11 | c.1805A>G p.K602R (on ENST00000403359 / NM_001190274.2; = p.K518R on NM_025133.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.796); catalogued as COSV57017118; called by muse, mutect2, varscan2
- FBXO21 | c.331C>T p.R111W | Missense Mutation (SNP) | VAF 48/170 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.551); catalogued as COSV57971926; called by muse, mutect2, varscan2
- FBXO22 | c.653G>A p.R218H | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs373656786; called by muse, mutect2, varscan2
- FCER2 | c.932G>A p.R311H | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.053); catalogued as rs149654388, COSV60915920; called by muse, mutect2, varscan2
- FCN2 | c.553G>A p.A185T | Missense Mutation (SNP) | VAF 12/79 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.017); catalogued as rs55860122, COSV52476166; called by muse, mutect2, varscan2
- FGD4 | c.1051C>T p.R351W | Missense Mutation (SNP) | VAF 77/262 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs567870963, COSV56781215; called by muse, mutect2, varscan2
- FGF20 | c.398T>G p.L133R | Missense Mutation (SNP) | VAF 44/338 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV51660954, COSV51661400; called by muse, mutect2, varscan2
- FGF5 | c.441del p.G148Efs*45 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | catalogued as rs35667286; called by mutect2, pindel, varscan2
- FGFR1 | c.1423C>T p.R475W (on ENST00000447712 / NM_023110.3; = p.R473W on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/254 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58329901; called by muse, mutect2, varscan2
- FH | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 35/126 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs587782207, COSV63817675; ClinVar: conflicting interpretations of pathogenicity / uncertain significance; called by muse, mutect2, varscan2
- FLG2 | c.2134A>G p.S712G | Missense Mutation (SNP) | VAF 93/565 reads (16%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0); catalogued as COSV66167154; called by muse, mutect2, varscan2
- FLG2 | c.886A>C p.S296R | Missense Mutation (SNP) | VAF 78/426 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); catalogued as COSV66167157; called by muse, mutect2, varscan2
- FLNA | c.2527dup p.A843Gfs*12 | Frame Shift Ins (INS) | VAF 22/205 reads (11%) | catalogued as rs782312089; called by mutect2, pindel, varscan2
- FLNB | c.6031G>A p.G2011S | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781212517, COSV55872921; called by muse, mutect2, varscan2
- FMN1 | c.2852T>G p.L951R (on ENST00000616417 / NM_001277313.2; = p.L728R on NM_001103184.4) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.35); PolyPhen benign (0.006); catalogued as COSV57919263; called by muse, mutect2, varscan2
- FN1 | c.2430G>A p.A810= | Splice Region (SNP) | VAF 30/105 reads (29%) | catalogued as rs751168230, COSV60548111; called by muse, mutect2, varscan2
- FN1 | c.1135C>T p.R379* | Nonsense Mutation (SNP) | VAF 33/180 reads (18%) | catalogued as COSV60548120; called by muse, mutect2, varscan2
- FNBP1 | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.922); catalogued as rs757294604, COSV63088323; called by muse, mutect2, varscan2
- FNDC3A | c.2597A>C p.E866A (on ENST00000492622 / NM_001079673.2; = p.E810A on NM_014923.5) | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV68132481; called by muse, mutect2, varscan2
- FOCAD | c.2791del p.S931Afs*11 | Frame Shift Del (DEL) | VAF 11/59 reads (19%) | catalogued as rs776730128; called by mutect2, pindel, varscan2
- FOXF2 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52525265; called by muse, mutect2, varscan2
- FREM2 | c.3172A>G p.T1058A | Missense Mutation (SNP) | VAF 36/267 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.281); catalogued as COSV54830907; called by muse, mutect2, varscan2
- FREM2 | c.5479C>T p.Q1827* | Nonsense Mutation (SNP) | VAF 28/59 reads (47%) | catalogued as COSV54830915; called by muse, mutect2, varscan2
- FRMD4A | c.3014del p.P1005Qfs*8 | Frame Shift Del (DEL) | VAF 44/128 reads (34%) | catalogued as rs752538869; called by mutect2, pindel, varscan2
- FRS2 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs945337284, COSV54723022, COSV54723848; called by muse, mutect2, varscan2
- FRS3 | c.712G>T p.G238C | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as COSV52484232; called by muse, mutect2, varscan2
- FSCN1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61017077; called by muse, mutect2, varscan2
- FYB1 | c.23dup p.N9Qfs*10 | Frame Shift Ins (INS) | VAF 49/130 reads (38%) | catalogued as rs747461552; called by mutect2, pindel, varscan2
- G3BP1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.011); catalogued as rs896356394, COSV62365718; called by muse, mutect2, varscan2
- GABPB2 | c.631del p.H211Mfs*42 | Frame Shift Del (DEL) | VAF 31/115 reads (27%) | catalogued as COSV100927191; called by mutect2, pindel, varscan2
- GABRA1 | c.233G>T p.G78V | Missense Mutation (SNP) | VAF 44/224 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV50099564; called by muse, mutect2, varscan2
- GABRR1 | c.1184C>T p.A395V | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs202214989, COSV65618946; called by muse, mutect2, varscan2
- GALNT11 | c.1202G>A p.R401Q | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746458339, COSV57424900; called by muse, mutect2, varscan2
- GALNT18 | c.1297G>T p.G433W | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57145341; called by muse, mutect2
- GALNT5 | c.647T>C p.L216S | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.021); catalogued as COSV52036316; called by muse, mutect2, varscan2
- GALNT5 | c.1861A>G p.N621D | Missense Mutation (SNP) | VAF 9/202 reads (4%) | SIFT tolerated (0.24); PolyPhen benign (0.113); catalogued as COSV52036323; called by muse, mutect2
- GDAP2 | c.413G>A p.R138H | Missense Mutation (SNP) | VAF 41/124 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs765915543, COSV65612045; called by muse, mutect2, varscan2
- GET3 | c.106A>G p.S36G | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV54406595; called by muse, mutect2, varscan2
- GIGYF1 | c.2818T>C p.Y940H | Missense Mutation (SNP) | VAF 12/232 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.692); catalogued as COSV51939878; called by muse, mutect2
- GINS1 | c.515del p.N172Ifs*14 | Frame Shift Del (DEL) | VAF 24/78 reads (31%) | catalogued as rs750227570; called by mutect2, varscan2
- GKN2 | c.317C>T p.A106V | Missense Mutation (SNP) | VAF 17/174 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.176); catalogued as rs1558706005, COSV61031002; called by muse, mutect2, varscan2
- GLI1 | c.821del p.G274Afs*6 | Frame Shift Del (DEL) | VAF 71/260 reads (27%) | catalogued as rs759448855, COSV99954330; called by mutect2, pindel, varscan2
- GLI1 | c.1628G>A p.S543N | Missense Mutation (SNP) | VAF 30/117 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.15); catalogued as COSV57358894; called by muse, mutect2, varscan2
- GLIS3 | c.2030A>C p.K677T | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60925383; called by muse, mutect2, varscan2
- GLS | c.1791T>C p.G597= | Splice Region (SNP) | VAF 10/174 reads (6%) | catalogued as COSV57840443; called by muse, mutect2
- GLYR1 | c.1140del p.R381Afs*20 | Frame Shift Del (DEL) | VAF 8/50 reads (16%) | catalogued as rs749150409; called by mutect2, varscan2
- GNAI2 | c.212C>T p.A71V | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as rs138213627, COSV56492950; called by muse, mutect2, varscan2
- GNG12 | c.202del p.T68Lfs*22 | Frame Shift Del (DEL) | VAF 44/198 reads (22%) | catalogued as rs1022402829; called by mutect2, pindel, varscan2
- GNL3L | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100328299, COSV60575641; called by muse, mutect2, varscan2
- GOLIM4 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 87/316 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs374445265; called by muse, mutect2, varscan2
- GORASP2 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 27/123 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV52201069; called by muse, mutect2, varscan2
- GOT2 | c.784C>T p.R262C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs752927520, COSV55330988; called by muse, mutect2, varscan2
- GPLD1 | c.2324G>A p.C775Y | Missense Mutation (SNP) | VAF 43/233 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57754883; called by muse, mutect2, varscan2
- GPR182 | c.931C>G p.L311V | Missense Mutation (SNP) | VAF 44/382 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.71); catalogued as COSV55625709; called by muse, mutect2, varscan2
- GRIK2 | c.2546del p.N849Tfs*14 | Frame Shift Del (DEL) | VAF 35/194 reads (18%) | catalogued as rs760757380; called by mutect2, varscan2
- GRIN1 | c.2442C>T p.A814= | Splice Region (SNP) | VAF 10/66 reads (15%) | catalogued as rs773708731, COSV100160378, COSV100160616; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIP1 | c.661A>G p.S221G | Missense Mutation (SNP) | VAF 51/211 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV54017209; called by muse, mutect2, varscan2
- GRM1 | c.2735G>A p.R912H | Missense Mutation (SNP) | VAF 52/118 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV51114084; called by muse, mutect2, varscan2
- GRM2 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs143196180; called by muse, mutect2, varscan2
- GRM3 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 9/45 reads (20%) | catalogued as rs891435292, COSV64467524; called by muse, mutect2, varscan2
- GRM5 | c.2716A>C p.T906P | Missense Mutation (SNP) | VAF 143/547 reads (26%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.282); catalogued as COSV59588196; called by muse, mutect2, varscan2
- GRM7 | c.458T>C p.V153A | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63133202; called by muse, mutect2, varscan2
- GRM7 | c.2444C>T p.A815V | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as rs201610100, COSV63133221; called by muse, mutect2, varscan2
- GSTO2 | c.368T>C p.V123A | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.313); catalogued as COSV58537824; called by muse, mutect2, varscan2
- GSTZ1 | c.298C>T p.R100C | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs774523538, COSV53623014; called by muse, mutect2, varscan2
- GTF2F1 | c.1427del p.K476Sfs*9 | Frame Shift Del (DEL) | VAF 42/251 reads (17%) | catalogued as COSV55532171; called by mutect2, pindel, varscan2
- GTF2H1 | c.1039C>T p.P347S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as COSV56377378; called by muse, mutect2, varscan2
- GTF2IRD1 | c.1616C>T p.T539I | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV56085024; called by muse, mutect2, varscan2
- GTF3C1 | c.976A>G p.T326A | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.872); catalogued as COSV62239498; called by muse, mutect2
- GTPBP10 | c.926dup p.N309Kfs*37 | Frame Shift Ins (INS) | VAF 16/86 reads (19%) | catalogued as rs745885335; called by mutect2, varscan2
- GUCY1A1 | c.162C>A p.N54K | Missense Mutation (SNP) | VAF 34/121 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV56649867; called by muse, mutect2, varscan2
- H1-1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.078); catalogued as COSV55118900; called by muse, mutect2, varscan2
- H4C7 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV55099486, COSV99769061; called by muse, mutect2, varscan2
- HABP2 | c.760A>C p.K254Q | Missense Mutation (SNP) | VAF 45/180 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.114); catalogued as COSV63636101; called by muse, mutect2, varscan2
- HABP2 | c.914A>G p.E305G | Missense Mutation (SNP) | VAF 60/236 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as COSV63636107; called by muse, mutect2, varscan2
- HACD4 | c.689del p.K230Rfs*45 | Frame Shift Del (DEL) | VAF 38/161 reads (24%) | catalogued as rs768797944; called by mutect2, varscan2
- HEATR1 | c.4166A>G p.H1389R | Missense Mutation (SNP) | VAF 15/76 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV63979985; called by muse, mutect2, varscan2
- HEATR3 | c.373A>C p.T125P | Missense Mutation (SNP) | VAF 100/417 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53528448; called by muse, mutect2, varscan2
- HEATR5B | c.3476G>A p.R1159Q | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0.097); catalogued as rs774406321, COSV51849995; called by muse, mutect2, varscan2
- HECA | c.1004dup p.H336Tfs*25 | Frame Shift Ins (INS) | VAF 27/166 reads (16%) | catalogued as rs771658394; called by mutect2, varscan2
- HGF | c.1427C>T p.T476I | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as COSV55946360; called by muse, mutect2, varscan2
- HHEX | c.451G>A p.E151K | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); catalogued as COSV51105846; called by muse, mutect2, varscan2
- HIP1R | c.397T>G p.Y133D | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53439894; called by muse, mutect2
- HK1 | c.2455G>A p.V819I | Missense Mutation (SNP) | VAF 20/65 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.439); catalogued as rs771865870, COSV53854807; called by muse, mutect2, varscan2
- HLA-A | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100954429, COSV65138189; called by muse, mutect2, varscan2
- HLA-DRA | c.353C>T p.T118I | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.188); catalogued as rs1407197550, COSV66622563; called by muse, mutect2, varscan2
- HLX | c.1106G>A p.R369H | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.05); PolyPhen benign (0.124); catalogued as rs754490132, COSV65044324; called by muse, mutect2, varscan2
- HMCN1 | c.16123T>C p.F5375L | Missense Mutation (SNP) | VAF 16/347 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1425366720, COSV54883460; called by muse, mutect2
- HMGCR | c.497C>T p.P166L | Missense Mutation (SNP) | VAF 29/593 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); catalogued as rs1371472683, COSV55314702; called by muse, mutect2
- HMSD | c.118C>T p.R40* | Nonsense Mutation (SNP) | VAF 47/210 reads (22%) | catalogued as rs761923017, COSV68816811; called by muse, mutect2, varscan2
- HNRNPCL1 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 55/236 reads (23%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); catalogued as COSV58610329; called by muse, mutect2, varscan2
- HNRNPUL1 | c.1859G>A p.R620H | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.921); catalogued as rs567506607, COSV54560573; called by muse, mutect2, varscan2
- HRNR | c.1775G>A p.G592E | Missense Mutation (SNP) | VAF 72/458 reads (16%) | SIFT tolerated (0.14); PolyPhen benign (0.273); catalogued as COSV64255240; called by muse, mutect2, varscan2
- HSDL2 | c.140A>G p.H47R | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV52713858; called by muse, mutect2
- HSPA12B | c.904G>T p.G302C | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.927); catalogued as COSV53923293; called by muse, mutect2, varscan2
- HTATSF1 | c.1503dup p.E502Rfs*3 | Frame Shift Ins (INS) | VAF 39/116 reads (34%) | catalogued as rs1374911912; called by mutect2, pindel, varscan2
- HTT | c.542G>A p.R181Q | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV61858501; called by muse, mutect2, varscan2
- HUS1B | c.280G>A p.A94T | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.657); catalogued as COSV57862159; called by muse, mutect2
- ICA1 | c.611del p.N204Tfs*5 | Frame Shift Del (DEL) | VAF 25/108 reads (23%) | catalogued as rs747841314; called by mutect2, varscan2
- IFI27L2 | c.7+2T>C p.X3_splice | Splice Site (SNP) | VAF 24/102 reads (24%) | catalogued as COSV99463102; called by muse, mutect2, varscan2
- IFI44 | c.794A>C p.D265A | Missense Mutation (SNP) | VAF 7/116 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as COSV66074240; called by muse, mutect2
- IFIT2 | c.470C>T p.A157V | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.266); catalogued as rs773713688, COSV51078205; called by muse, mutect2, varscan2
- IFNA4 | c.321A>T p.K107N | Missense Mutation (SNP) | VAF 42/238 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as COSV101427066; called by muse, mutect2, varscan2
- IFRD1 | c.916dup p.Y306Lfs*2 | Frame Shift Ins (INS) | VAF 32/116 reads (28%) | catalogued as rs979653918; called by mutect2, varscan2
- IFT122 | c.2909G>A p.R970H (on ENST00000348417 / NM_052989.3; = p.R911H on NM_018262.4) | Missense Mutation (SNP) | VAF 67/275 reads (24%) | SIFT tolerated (0.42); PolyPhen benign (0.082); catalogued as rs762874935, COSV56200574; called by muse, varscan2
- IGF2R | c.3650G>T p.C1217F | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63626961; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 101/357 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.971); catalogued as rs376195911; called by muse, mutect2, varscan2
- IGKV2D-24 | c.248T>C p.V83A | Missense Mutation (SNP) | VAF 55/270 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as rs1168709454; called by muse, mutect2, varscan2
- IGSF1 | c.2795T>A p.V932D | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV63836518; called by muse, mutect2, varscan2
- IGSF9 | c.154dup p.L52Pfs*27 | Frame Shift Ins (INS) | VAF 7/27 reads (26%) | catalogued as rs753928344; called by mutect2, varscan2
- IL1F10 | c.116C>T p.A39V | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.457); catalogued as rs1461946620, COSV61750374; called by muse, mutect2, varscan2
- IL21 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as rs141748932; called by muse, mutect2, varscan2
- IL2RA | c.689T>C p.M230T | Missense Mutation (SNP) | VAF 37/159 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV56919928; called by muse, mutect2, varscan2
- ILDR2 | c.1379C>T p.S460L | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.078); catalogued as rs1272156965; called by muse, varscan2
- INPPL1 | c.2927dup p.P977Tfs*7 | Frame Shift Ins (INS) | VAF 40/191 reads (21%) | catalogued as rs749079348; called by mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 7/31 reads (23%) | catalogued as rs760925109; called by mutect2, pindel, varscan2
- INSC | c.868C>T p.R290W | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as rs373439305; called by mutect2, varscan2
- INTS1 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762120974, COSV67176622; called by muse, mutect2, varscan2
- IRAK1 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 15/68 reads (22%) | catalogued as COSV64110180; called by muse, mutect2, varscan2
- IRF2 | c.122C>T p.A41V | Missense Mutation (SNP) | VAF 38/178 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1255904730, COSV66928316; called by muse, varscan2
- IRS4 | c.3110G>A p.R1037H | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.642); catalogued as COSV64532944; called by muse, mutect2, varscan2
- ISG20 | c.344T>G p.L115R | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.07); catalogued as COSV60143439; called by muse, mutect2, varscan2
- ITGB1BP2 | c.344C>T p.P115L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.662); catalogued as rs376350791, COSV52136110; called by muse, mutect2, varscan2
- ITGB3 | c.986del p.N329Tfs*4 | Frame Shift Del (DEL) | VAF 48/202 reads (24%) | catalogued as COSV71384954; called by mutect2, pindel, varscan2
- ITIH5 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as rs112992012; called by muse, mutect2, varscan2
- ITPR2 | c.7216G>A p.V2406I | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV67266122; called by muse, mutect2, varscan2
- IZUMO2 | c.205G>A p.A69T | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs1417194030, COSV53229360; called by muse, mutect2, varscan2
- JAML | c.202G>A p.E68K (on ENST00000356289 / NM_001098526.2; = p.E58K on NM_153206.3) | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs1201784659, COSV52626722; called by muse, mutect2, varscan2
- JCAD | c.2137C>T p.P713S | Missense Mutation (SNP) | VAF 6/94 reads (6%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV64758379; called by muse, mutect2
- JMJD1C | c.450C>T p.D150= | Splice Region (SNP) | VAF 28/116 reads (24%) | catalogued as rs745506808, COSV67858786; ClinVar: likely benign; called by muse, mutect2, varscan2
- JRKL | c.1069T>C p.W357R | Missense Mutation (SNP) | VAF 32/198 reads (16%) | SIFT tolerated (0.8); PolyPhen probably damaging (0.948); catalogued as COSV53592476, COSV53594098; called by muse, mutect2, varscan2
- KANK4 | c.217T>G p.F73V | Missense Mutation (SNP) | VAF 58/238 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV62985195, COSV62988001; called by muse, mutect2, varscan2
- KANSL1 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 24/78 reads (31%) | catalogued as COSV52264743; called by muse, mutect2, varscan2
- KAT6B | c.4906A>G p.I1636V | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as COSV54743461; called by muse, mutect2, varscan2
- KAT6B | c.5218A>C p.I1740L | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.056); catalogued as COSV54743473; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 29/172 reads (17%) | catalogued as rs774820321; called by mutect2, varscan2
- KCNA2 | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 50/164 reads (30%) | catalogued as COSV60369277; called by muse, mutect2, varscan2
- KCNB2 | c.435del p.E146Nfs*3 | Frame Shift Del (DEL) | VAF 72/202 reads (36%) | catalogued as rs752059864; called by mutect2, varscan2
- KCNC4 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1417916529, COSV63925219, COSV63926097; called by muse, mutect2, varscan2
- KCNG2 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs919202700, COSV60266951; called by muse, mutect2, varscan2
- KCNG3 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.832); catalogued as COSV100045128; called by muse, varscan2
- KCNJ10 | c.182A>G p.D61G | Missense Mutation (SNP) | VAF 45/181 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.372); catalogued as COSV63633038; called by muse, mutect2, varscan2
- KCNT1 | c.569G>A p.R190H (on ENST00000488444; = p.R209H on NM_020822.3) | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs756952430, COSV99705943; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCTD10 | c.922C>T p.R308W | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); catalogued as rs778658209, COSV57326088; called by muse, varscan2
- KCTD10 | c.886C>T p.R296C | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs991352796, COSV57326101; called by muse, varscan2
- KDM2A | c.1480A>G p.I494V | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV58188819; called by muse, mutect2, varscan2
- KDM5A | c.3122C>T p.P1041L | Missense Mutation (SNP) | VAF 44/158 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs564426386, COSV66990742; called by muse, mutect2, varscan2
- KHDC4 | c.469C>T p.R157C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs542119476, COSV64164650; called by muse, mutect2, varscan2
- KIAA0100 | c.4667T>C p.M1556T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as COSV66491096; called by muse, mutect2, varscan2
- KIAA0319 | c.2006T>C p.V669A | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.761); catalogued as rs1475024381, COSV65496891; called by muse, mutect2, varscan2
- KIF17 | c.694C>T p.R232W | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756868351, COSV56117884; called by muse, mutect2, varscan2
- KIF19 | c.1268G>A p.R423Q | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.206); catalogued as rs1277165700, COSV100739087; called by muse, varscan2
- KIF20A | c.1282G>T p.G428* | Nonsense Mutation (SNP) | VAF 12/98 reads (12%) | catalogued as COSV67509422; called by muse, mutect2, varscan2
- KIF21B | c.4166C>T p.S1389L (on ENST00000422435 / NM_001252100.2; = p.S1376L on NM_017596.4) | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs749063098, COSV59753591; called by muse, mutect2, varscan2
- KIF23 | c.1228A>G p.I410V | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.487); catalogued as COSV52977865; called by muse, mutect2, varscan2
- KIF6 | c.611del p.L204* | Frame Shift Del (DEL) | VAF 22/104 reads (21%) | catalogued as rs777890702; called by mutect2, pindel, varscan2
- KLHDC4 | c.1069C>T p.R357C | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs770378718, COSV54506450; called by muse, mutect2, varscan2
- KLHL14 | c.1087G>A p.A363T | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.992); catalogued as COSV100839223; called by muse, mutect2, varscan2
- KMT2E | c.691del p.S231Afs*73 | Frame Shift Del (DEL) | VAF 23/142 reads (16%) | catalogued as rs1207852808; called by mutect2, varscan2
- KNTC1 | c.2413T>C p.Y805H | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.55); PolyPhen benign (0.014); catalogued as COSV61079190; called by muse, mutect2, varscan2
- KRT10 | c.1276G>A p.E426K | Missense Mutation (SNP) | VAF 66/225 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as rs1409868625, COSV54088905, COSV54090327, COSV99510056; called by muse, mutect2, varscan2
- KRT2 | c.473G>A p.S158N | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.638); catalogued as COSV59009420; called by muse, mutect2, varscan2
- KRT85 | c.647C>T p.A216V | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.034); catalogued as COSV57736181; called by muse, mutect2, varscan2
- LAMA1 | c.1487del p.N496Tfs*27 | Frame Shift Del (DEL) | VAF 41/219 reads (19%) | catalogued as rs1406609727; called by mutect2, pindel, varscan2
- LAMA3 | c.3358C>T p.R1120C | Missense Mutation (SNP) | VAF 45/232 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as rs778909276, COSV58063847; called by muse, mutect2, varscan2
- LAMA4 | c.3149A>G p.Y1050C (on ENST00000230538 / NM_001105206.3; = p.Y1043C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57892941; called by muse, mutect2
- LANCL2 | c.1021_1023del p.E341del | In Frame Del (DEL) | VAF 17/101 reads (17%) | catalogued as rs757658653; called by pindel, varscan2
- LANCL3 | c.967T>C p.C323R | Missense Mutation (SNP) | VAF 25/112 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as rs1285415584, COSV66127949; called by muse, varscan2
- LARP1 | c.906dup p.T303Hfs*19 (on ENST00000518297 / NM_033551.3; = p.T226Hfs*19 on NM_015315.5 and 6 other RefSeq transcripts) | Frame Shift Ins (INS) | VAF 52/322 reads (16%) | catalogued as rs769338468; called by mutect2, varscan2
- LATS2 | c.503C>T p.T168M | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.425); catalogued as rs1163593629, COSV66873953; called by muse, mutect2, varscan2
- LCAT | c.490C>T p.R164C | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1380009545, CM043857, COSV50452203; called by muse, mutect2, varscan2
- LCE1E | c.4T>G p.S2A | Missense Mutation (SNP) | VAF 74/317 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV64219592; called by muse, mutect2, varscan2
- LCMT2 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.027); catalogued as COSV59789751; called by muse, mutect2, varscan2
- LGALS4 | c.719G>A p.R240H | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs371360675; called by muse, mutect2, varscan2
- LHX8 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.027); catalogued as COSV53954913; called by muse, mutect2, varscan2
- LIMK1 | c.1634G>A p.R545Q | Missense Mutation (SNP) | VAF 60/238 reads (25%) | SIFT tolerated (0.19); PolyPhen benign (0.228); catalogued as rs782125431, COSV60280307; called by muse, mutect2, varscan2
- LINGO2 | c.1477A>G p.T493A | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV58057958; called by muse, mutect2, varscan2
- LIPT1 | c.368del p.K123Sfs*8 | Frame Shift Del (DEL) | VAF 28/98 reads (29%) | catalogued as rs780042765; called by mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 40/148 reads (27%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LMBR1 | c.965A>C p.D322A | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV62218730; called by muse, mutect2
- LMOD3 | c.998G>A p.C333Y | Missense Mutation (SNP) | VAF 91/377 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1249266090, COSV70455768; called by muse, mutect2, varscan2
- LMOD3 | c.61G>A p.D21N | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as COSV70455775; called by muse, mutect2, varscan2
- LONP1 | c.1519G>A p.V507I | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.84); catalogued as rs143983421; called by muse, mutect2, varscan2
- LRBA | c.4364G>A p.C1455Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs772088099, COSV63951149; called by muse, mutect2, varscan2
- LRIG2 | c.1798+2T>C p.X600_splice | Splice Site (SNP) | VAF 11/71 reads (15%) | catalogued as COSV63161276; called by muse, mutect2
- LRP1 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 72/269 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV54504237; called by muse, mutect2, varscan2
- LRRC4 | c.1072G>A p.A358T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.085); catalogued as rs200804366, COSV50813271; called by muse, mutect2, varscan2
- LRRN3 | c.475G>A p.A159T | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57817960; called by muse, mutect2
- LY75 | c.4235del p.K1412Rfs*2 | Frame Shift Del (DEL) | VAF 23/113 reads (20%) | catalogued as rs1301982151; called by mutect2, pindel, varscan2
- LYPD2 | c.11C>T p.T4M | Missense Mutation (SNP) | VAF 16/107 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs377300661; called by muse, mutect2, varscan2
- LYST | c.7877T>C p.M2626T | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.889); catalogued as COSV101089684; called by muse, mutect2, varscan2
- LZTR1 | c.311C>G p.S104C | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53145725, COSV99302293; called by muse, mutect2, varscan2
- LZTS1 | c.292T>A p.F98I | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.395); catalogued as COSV56115746, COSV56116081; called by muse, mutect2, varscan2
- MACO1 | c.306dup p.A103Cfs*3 | Frame Shift Ins (INS) | VAF 30/93 reads (32%) | catalogued as rs752439249; called by mutect2, varscan2
- MADD | c.4323G>T p.Q1441H | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV60621275; called by muse, mutect2, varscan2
- MAGEA10 | c.50A>G p.Q17R | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV54883165; called by muse, mutect2
- MAGEA8 | c.325C>T p.R109W | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.945); catalogued as rs782441821, COSV54063772; called by muse, mutect2
- MAGED2 | c.1069G>A p.A357T | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.808); catalogued as COSV54497142; called by muse, mutect2
- MAGI2 | c.1694C>T p.P565L | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs779649509, COSV100833252, COSV62639405; called by muse, mutect2, varscan2
- MAMSTR | c.485dup p.H163Tfs*9 (on ENST00000318083 / NM_001130915.2; = p.H60Tfs*9 on NM_182574.2) | Frame Shift Ins (INS) | VAF 38/147 reads (26%) | catalogued as rs752869239; called by mutect2, varscan2
- MAN1B1 | c.1886G>A p.R629Q | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.112); catalogued as rs200910068, COSV65371034; called by muse, mutect2, varscan2
- MANEA | c.749C>T p.A250V | Missense Mutation (SNP) | VAF 21/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62589335; called by muse, mutect2, varscan2
- MAOA | c.608del p.G203Afs*18 | Frame Shift Del (DEL) | VAF 49/210 reads (23%) | catalogued as COSV58644680; called by mutect2, pindel, varscan2
- MAP1S | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.059); catalogued as rs752078894, COSV60721947; called by muse, mutect2, varscan2
- MAP2K4 | c.277C>T p.Q93* | Nonsense Mutation (SNP) | VAF 35/136 reads (26%) | catalogued as COSV62255471; called by muse, mutect2, varscan2
- MAP2K4 | c.814C>T p.P272S | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62255478, COSV62261455; called by muse, mutect2, varscan2
- MAP7D2 | c.184C>T p.R62* | Nonsense Mutation (SNP) | VAF 47/143 reads (33%) | catalogued as COSV65526028; called by muse, mutect2, varscan2
- MAPK15 | c.1120G>A p.D374N | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs371482487; called by muse, mutect2, varscan2
- MARCKSL1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.454); catalogued as COSV61481876; called by muse, mutect2, varscan2
- MAST1 | c.877-1G>T p.X293_splice | Splice Site (SNP) | VAF 12/148 reads (8%) | catalogued as COSV52242410; called by muse, mutect2
- MAST1 | c.2105G>A p.R702H | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.035); catalogued as rs759443859, COSV52242416; called by muse, mutect2, varscan2
- MAST1 | c.3629C>T p.T1210M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1160779669, COSV52242425; called by muse, mutect2, varscan2
- MCC | c.2170A>G p.T724A | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56725086; called by muse, mutect2
- MCF2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.04); catalogued as COSV58479664; called by muse, mutect2, varscan2
- MDC1 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.24); catalogued as rs771893736, COSV64523686; called by muse, mutect2, varscan2
- MDGA1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1197290238, COSV51792850; called by muse, mutect2, varscan2
- MDN1 | c.5966del p.K1989Rfs*65 | Frame Shift Del (DEL) | VAF 68/390 reads (17%) | catalogued as rs750092100; called by mutect2, varscan2
- MED12L | c.2998C>A p.L1000I | Missense Mutation (SNP) | VAF 82/313 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.967); catalogued as COSV56371458; called by muse, mutect2, varscan2
- MEGF8 | c.497del p.G166Vfs*53 | Frame Shift Del (DEL) | VAF 8/35 reads (23%) | catalogued as rs762115034; called by mutect2, pindel, varscan2
- MGAT3 | c.1193G>A p.R398H | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.322); catalogued as COSV57864392; called by muse, mutect2, varscan2
- MICB | c.326-1G>T p.X109_splice | Splice Site (SNP) | VAF 19/41 reads (46%) | catalogued as COSV99357456; called by muse, mutect2, varscan2
- MIER2 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.425); catalogued as rs776173360, COSV53394106; called by muse, mutect2, varscan2
- MLLT1 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 23/99 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as COSV53129562; called by muse, mutect2, varscan2
- MLLT10 | c.2359G>A p.A787T (on ENST00000307729 / NM_001195626.3; = p.A803T on NM_004641.3) | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV56992544; called by muse, mutect2, varscan2
- MOGAT3 | c.616T>A p.C206S | Missense Mutation (SNP) | VAF 7/123 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as rs1157292735, COSV56173052; called by muse, mutect2
- MON1A | c.596C>T p.T199M | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as rs754159971, COSV56559592; called by muse, mutect2, varscan2
- MORC1 | c.2641del p.I881* | Frame Shift Del (DEL) | VAF 28/100 reads (28%) | catalogued as rs757379917; called by mutect2, varscan2
- MOS | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV61336014; called by muse, mutect2, varscan2
- MPDZ | c.5815T>C p.S1939P (on ENST00000319217 / NM_001330637.2; = p.S1910P on NM_003829.5) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV59915927; called by muse, mutect2, varscan2
- MPDZ | c.856C>A p.P286T | Missense Mutation (SNP) | VAF 25/125 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1278326524, COSV59936769; called by muse, mutect2, varscan2
- MPP2 | c.1183A>G p.I395V (on ENST00000461854 / NM_001278372.2; = p.I371V on NM_005374.5) | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.258); catalogued as rs1228413294, COSV52233964; called by muse, mutect2, varscan2
- MPP6 | c.917del p.K306Rfs*4 | Frame Shift Del (DEL) | VAF 36/189 reads (19%) | catalogued as rs757450051; ClinVar: not provided; called by mutect2, varscan2
- MRPL50 | c.92+2T>C p.X31_splice | Splice Site (SNP) | VAF 68/278 reads (24%) | catalogued as COSV99407215; called by muse, mutect2, varscan2
- MRTFA | c.1220del p.P407Qfs*30 | Frame Shift Del (DEL) | VAF 26/124 reads (21%) | catalogued as rs34028511; called by mutect2, pindel, varscan2
- MTF1 | c.751C>T p.R251* | Nonsense Mutation (SNP) | VAF 34/142 reads (24%) | catalogued as COSV65988552; called by muse, varscan2
- MTHFD1L | c.1806G>A p.A602= | Splice Region (SNP) | VAF 41/115 reads (36%) | catalogued as rs146093887; called by muse, mutect2, varscan2
- MTHFSD | c.919G>A p.D307N (on ENST00000360900 / NM_001159377.2; = p.D306N on NM_022764.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV59802464; called by muse, mutect2, varscan2
- MTMR1 | c.1949G>A p.R650Q | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.493); catalogued as rs1313706639, COSV60935229; called by muse, mutect2, varscan2
- MTMR3 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 101/602 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs752456939, COSV60302271; called by muse, mutect2, varscan2
- MTTP | c.854C>T p.T285M | Missense Mutation (SNP) | VAF 30/147 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.224); catalogued as rs566965111, COSV55504376; called by muse, varscan2
- MUC16 | c.35382A>C p.Q11794H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.005); catalogued as COSV67451419; called by muse, mutect2, varscan2
- MUC5B | c.5728C>A p.P1910T | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1242892839, COSV71590463; called by muse, mutect2, varscan2
- MUC5B | c.6612del p.S2205Afs*29 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | catalogued as COSV71590202; called by mutect2, pindel
- MUC6 | c.2974C>A p.R992S | Missense Mutation (SNP) | VAF 48/173 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV70136147; called by muse, mutect2, varscan2
- MXRA5 | c.6076G>A p.V2026M | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as rs375991615, COSV54237684; called by muse, mutect2, varscan2
- MYBPC1 | c.311G>A p.S104N (on ENST00000550270 / NM_206820.2; = p.S129N on NM_002465.4) | Missense Mutation (SNP) | VAF 7/160 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as COSV62251542; called by muse, mutect2
- MYCT1 | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT tolerated (0.73); PolyPhen benign (0.181); catalogued as COSV65890923; called by muse, mutect2, varscan2
- MYH6 | c.5299A>G p.M1767V | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV59305059; called by muse, mutect2, varscan2
- MYH8 | c.2799A>C p.E933D | Missense Mutation (SNP) | VAF 23/786 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV67961160; called by muse, mutect2
- MYH9 | c.4009G>A p.E1337K | Missense Mutation (SNP) | VAF 28/153 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs1038334022, COSV53383007; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH9 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 100/410 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs202023656, COSV53393696; called by muse, mutect2, varscan2
- MYH9 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 104/411 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1156464508, COSV99339063; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYOCD | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 32/174 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.08); catalogued as COSV100590883; called by mutect2, varscan2
- MYOF | c.3508C>A p.H1170N | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.95); catalogued as COSV63701406; called by muse, mutect2, varscan2
- NAT10 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 36/148 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as rs887949387, COSV57662694; called by muse, mutect2, varscan2
- NAXD | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59393771; called by muse, mutect2, varscan2
- NAXE | c.291+2T>G p.X97_splice | Splice Site (SNP) | VAF 6/78 reads (8%) | catalogued as COSV63992398; called by muse, mutect2
- NCAN | c.1265A>C p.K422T | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT tolerated (0.31); PolyPhen benign (0.007); catalogued as COSV53047779; called by muse, mutect2, varscan2
- NCAPG2 | c.161T>C p.L54P | Missense Mutation (SNP) | VAF 9/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV51985391; called by muse, mutect2
- NCDN | c.1969G>A p.A657T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.446); catalogued as rs752708609, COSV61934916; called by muse, mutect2
- NCKAP5 | c.5078A>T p.E1693V | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.403); catalogued as COSV58432012; called by muse, mutect2, varscan2
- NCKAP5 | c.2096A>T p.N699I | Missense Mutation (SNP) | VAF 12/250 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV58432030; called by muse, mutect2
- NCKAP5L | c.2719G>A p.A907T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs769925783, COSV60127995; called by muse, mutect2
- NCOA7 | c.209del p.K70Rfs*7 | Frame Shift Del (DEL) | VAF 159/420 reads (38%) | catalogued as rs749319230; called by mutect2, varscan2
- NCOR2 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62294586; called by muse, mutect2, varscan2
- NCOR2 | c.411+2T>C p.X137_splice | Splice Site (SNP) | VAF 7/16 reads (44%) | catalogued as COSV62294594; called by muse, mutect2, varscan2
- NCSTN | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV54185595, COSV54191694; called by muse, mutect2, varscan2
- NDN | c.784T>C p.W262R | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59358705; called by muse, varscan2
- NDST1 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 50/213 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs746465319, COSV55785316; called by muse, mutect2, varscan2
- NDST1 | c.1792G>A p.E598K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.259); catalogued as COSV55785321; called by muse, mutect2, varscan2
- NEB | c.14473G>A p.D4825N | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs201731351; called by muse, mutect2, varscan2
- NEK9 | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 40/164 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs192831803; called by muse, mutect2, varscan2
- NELFE | c.689G>A p.R230Q | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.042); catalogued as rs373090703; called by muse, mutect2, varscan2
- NEXMIF | c.3353C>T p.T1118I | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV50023247; called by muse, mutect2, varscan2
- NFE2L1 | c.2020C>T p.R674C | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs369510266; called by muse, mutect2, varscan2
- NFKBIZ | c.1888C>T p.R630C | Missense Mutation (SNP) | VAF 48/222 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1198660404, COSV58199654; called by muse, varscan2
- NFRKB | c.1832C>T p.A611V (on ENST00000446488 / NM_001143835.2; = p.A636V on NM_006165.3) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV58756806; called by muse, varscan2
- NFRKB | c.932del p.K311Rfs*13 (on ENST00000446488 / NM_001143835.2; = p.K336Rfs*13 on NM_006165.3) | Frame Shift Del (DEL) | VAF 42/143 reads (29%) | catalogued as rs149369172, COSV58756820; called by mutect2, varscan2
- NFX1 | c.1673T>C p.L558S | Missense Mutation (SNP) | VAF 26/618 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0.096); catalogued as COSV59308751; called by muse, mutect2
- NGEF | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.054); catalogued as rs141871026; called by muse, mutect2, varscan2
- NGEF | c.988C>T p.R330W | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as rs761455816, COSV50915509; called by muse, mutect2, varscan2
- NHS | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1005975272, COSV66272351; called by muse, mutect2, varscan2
- NIBAN2 | c.620C>A p.P207H | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); catalogued as COSV64823842, COSV64824949; called by muse, mutect2
- NID2 | c.2940C>A p.F980L | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.091); catalogued as COSV53493896; called by muse, mutect2, varscan2
- NKD1 | c.1234G>T p.G412C | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.421); catalogued as COSV51689953; called by muse, mutect2, varscan2
- NKD2 | c.944G>A p.R315Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs375289481, COSV56890246; called by muse, mutect2, varscan2
- NKPD1 | c.1907T>A p.L636Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1438316151, COSV58727882; called by muse, mutect2
- NKX2-3 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.644); catalogued as COSV60728422; called by muse, mutect2
- NLGN1 | c.371G>A p.G124D | Missense Mutation (SNP) | VAF 71/318 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.056); catalogued as COSV64325767; called by muse, mutect2, varscan2
- NLRP1 | c.1748del p.K583Rfs*14 | Frame Shift Del (DEL) | VAF 18/75 reads (24%) | catalogued as COSV52567752; called by mutect2, pindel, varscan2
- NLRP4 | c.1087C>A p.L363M | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.79); catalogued as COSV56709862; called by muse, mutect2, varscan2
- NLRP5 | c.427C>T p.R143W | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs201123213, COSV66761888; called by muse, mutect2, varscan2
- NLRP6 | c.1709G>A p.R570H | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs768823068, COSV100381039; called by muse, mutect2, varscan2
- NLRP6 | c.1987G>A p.V663M | Missense Mutation (SNP) | VAF 38/145 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs1490499073, COSV56458499, COSV56462673; called by muse, mutect2, varscan2
- NOL6 | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as rs1449210177, COSV53039760; called by muse, mutect2
- NOMO1 | c.2945C>T p.A982V | Missense Mutation (SNP) | VAF 46/230 reads (20%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs1314814799, COSV55058065; called by muse, mutect2, varscan2
- NOMO1 | c.3082C>T p.R1028W | Missense Mutation (SNP) | VAF 34/204 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1228317582, COSV55061225; called by muse, mutect2, varscan2
- NOS2 | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); catalogued as COSV58222373, COSV58224902; called by muse, mutect2, varscan2
- NPAS3 | c.1901C>T p.P634L (on ENST00000356141 / NM_001164749.2; = p.P602L on NM_022123.3) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.199); catalogued as rs1185500585, COSV60824886; called by muse, mutect2
- NPBWR1 | c.260C>T p.T87M | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs1384343664, COSV58695591; called by muse, mutect2, varscan2
- NR3C2 | c.2215G>A p.V739I | Missense Mutation (SNP) | VAF 64/254 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as rs553995203, COSV60986618, COSV60999595; called by muse, mutect2, varscan2
- NR4A2 | c.1414A>T p.R472W | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59892938; called by muse, mutect2
- NRIP1 | c.2184del p.E729Rfs*5 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | catalogued as rs776154715; called by mutect2, varscan2
- NRP2 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.026); catalogued as rs769522962, COSV55924480, COSV99786123; called by muse, mutect2
- NRXN3 | c.1247G>A p.R416H (on ENST00000335750 / NM_001330195.2; = p.R43H on NM_004796.6) | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs780387298, COSV59713183, COSV59750859; called by muse, mutect2, varscan2
- NSD2 | c.2185C>T p.R729C | Missense Mutation (SNP) | VAF 97/302 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56387591; called by muse, mutect2, varscan2
- NSMF | c.866G>A p.R289Q (on ENST00000371475 / NM_001130969.3; = p.R287Q on NM_015537.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.975); catalogued as rs1214341527, COSV55809950; called by muse, mutect2, varscan2
- NSUN5 | c.74T>C p.V25A | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.138); catalogued as COSV53090681; called by muse, mutect2, varscan2
- NUDT13 | c.914T>A p.V305E | Missense Mutation (SNP) | VAF 7/104 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV61968261; called by muse, mutect2
- NUP85 | c.1231T>C p.F411L | Missense Mutation (SNP) | VAF 11/168 reads (7%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.74); catalogued as COSV55455628; called by muse, mutect2
- NUP88 | c.1862G>A p.R621H | Missense Mutation (SNP) | VAF 74/333 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs774967326, COSV52583140; called by muse, mutect2, varscan2
- NUTF2 | c.380G>A p.G127D | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.297); catalogued as COSV54645375; called by muse, mutect2, varscan2
- OBSCN | c.5666C>T p.A1889V | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.876); catalogued as rs752268935, COSV99486394; called by muse, mutect2
- OCA2 | c.1657G>A p.V553I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.572); catalogued as rs552418165, COSV62339253, COSV62347333; called by muse, mutect2, varscan2
- ODF2L | c.1221del p.K407Nfs*22 (on ENST00000317336; = p.K378Nfs*22 on NM_020729.3) | Frame Shift Del (DEL) | VAF 20/62 reads (32%) | catalogued as rs761049141, COSV54018443; called by mutect2, varscan2
- OGDH | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 82/321 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as COSV56046497; called by muse, mutect2, varscan2
- OR10G7 | c.355T>C p.Y119H | Missense Mutation (SNP) | VAF 40/228 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV57865779; called by muse, mutect2, varscan2
- OR10Z1 | c.535del p.C179Vfs*7 | Frame Shift Del (DEL) | VAF 44/183 reads (24%) | catalogued as rs755391413; called by mutect2, pindel, varscan2
- OR14C36 | c.315del p.F105Lfs*28 | Frame Shift Del (DEL) | VAF 14/64 reads (22%) | catalogued as rs761899382; called by mutect2, varscan2
- OR2A2 | c.565G>A p.A189T | Missense Mutation (SNP) | VAF 44/353 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.461); catalogued as COSV68871214; called by muse, mutect2, varscan2
- OR4P4 | c.315del p.F105Lfs*4 | Frame Shift Del (DEL) | VAF 43/191 reads (23%) | catalogued as rs748398423; called by mutect2, pindel, varscan2
- OR52E8 | c.559C>T p.H187Y | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV66205242; called by muse, mutect2, varscan2
- OR52L1 | c.878T>A p.L293H | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV59986082; called by muse, mutect2, varscan2
- OR5L1 | c.157T>C p.S53P | Missense Mutation (SNP) | VAF 109/397 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV61733026, COSV61733519; called by muse, mutect2, varscan2
- OR5V1 | c.271del p.S91Afs*18 | Frame Shift Del (DEL) | VAF 75/221 reads (34%) | catalogued as rs754676491; called by mutect2, pindel, varscan2
- OR8S1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | PolyPhen benign (0); catalogued as rs373769388, COSV59599539; called by muse, mutect2, varscan2
- ORC1 | c.2381C>T p.T794M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs767782494, COSV65363435; called by muse, mutect2, varscan2
- ORC3 | c.1061_1063del p.R354del | In Frame Del (DEL) | VAF 20/150 reads (13%) | catalogued as rs1384876082; called by pindel, varscan2
- OSBPL8 | c.1072T>A p.S358T | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.168); catalogued as COSV53879384; called by muse, mutect2, varscan2
- OTOF | c.5461G>A p.E1821K (on ENST00000272371 / NM_194248.3; = p.E1054K on NM_004802.4) | Missense Mutation (SNP) | VAF 58/217 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs756694424, COSV55497873, COSV99716828; called by muse, mutect2, varscan2
- P2RX2 | c.741G>T p.K247N (on ENST00000343948 / NM_170683.4; = p.K175N on NM_012226.5) | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.158); catalogued as COSV57675745; called by muse, mutect2, varscan2
- P4HB | c.1160del p.N387Tfs*118 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | catalogued as rs763394045; called by mutect2, varscan2
- PACRGL | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 15/77 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.061); catalogued as rs753347278, COSV54841678, COSV99764249; called by muse, mutect2, varscan2
- PAFAH1B2 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 14/396 reads (4%) | catalogued as COSV59166493; called by muse, mutect2
- PAK6 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as rs369825628, COSV53045044; called by muse, mutect2, varscan2
- PAMR1 | c.302del p.G101Vfs*8 | Frame Shift Del (DEL) | VAF 99/430 reads (23%) | catalogued as rs751755759; called by mutect2, pindel, varscan2
- PAPPA | c.1320C>G p.C440W | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60278783, COSV60292035; called by muse, mutect2, varscan2
- PARN | c.1816A>G p.K606E | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.024); catalogued as COSV58364293; called by muse, mutect2, varscan2
- PARP10 | c.2347C>T p.R783C | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs781999070, COSV57296906, COSV57299465; called by muse, mutect2, varscan2
- PASD1 | c.1136A>C p.K379T | Missense Mutation (SNP) | VAF 176/408 reads (43%) | SIFT tolerated (0.19); PolyPhen benign (0.207); catalogued as COSV64854421; called by muse, mutect2, varscan2
- PATJ | c.4125+2T>C p.X1375_splice | Splice Site (SNP) | VAF 13/64 reads (20%) | catalogued as rs989145805, COSV56247908; called by muse, mutect2
- PATZ1 | c.110G>A p.G37D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53228895; called by muse, mutect2, varscan2
- PCBP4 | c.226G>A p.V76I | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.388); catalogued as rs936703345, COSV59053903; called by muse, mutect2, varscan2
1,061 further variants in this file (664 protein-altering or splice-affecting, 350 silent, 47 other) are not listed here.
